Somatic mutation profile of tumor specimen TCGA-W3-A825-06A (aliquot TCGA-W3-A825-06A-11D-A34U-08) from TCGA case TCGA-W3-A825, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 65.0 years (23,741 days).
Specimen TCGA-W3-A825-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 62631bb1-1d89-419b-b22b-7a3a07799bd7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-W3-A825-10A (Blood Derived Normal), aliquot TCGA-W3-A825-10A-01D-A34X-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/239e5e8d-8b14-486c-9f94-6dc3064b8e59

The open-access MAF lists 1,354 somatic variants for this specimen: 878 protein-altering or splice-affecting, 434 silent, 42 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 791, Silent 434, Nonsense Mutation 52, Intron 22, Splice Region 15, RNA 10, Splice Site 8, 5'Flank 7, Translation Start Site 4, Frame Shift Del 3, 5'UTR 3, In Frame Del 3.

Variants (750 of 1,354; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNA11 | c.547C>T p.R183C | Missense Mutation (SNP) | VAF 63/162 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1555702147, COSV50017316; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KCNJ8 | c.1250G>A p.G417E | Missense Mutation (SNP) | VAF 47/130 reads (36%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.131); catalogued as COSV53715303; called by muse, mutect2, varscan2
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 57/80 reads (71%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PPP6C | c.790C>T p.R264C | Missense Mutation (SNP) | VAF 27/49 reads (55%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763733111, COSV65207035; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AATK | c.2929A>G p.T977A (on ENST00000326724 / NM_001080395.3; = p.T874A on NM_004920.2) | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated (0.11); PolyPhen benign (0.014); catalogued as COSV100353269; called by muse, mutect2, varscan2
- ABCA12 | c.2314G>A p.G772R (on ENST00000272895 / NM_173076.3; = p.G454R on NM_015657.3) | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.859); catalogued as COSV99792109; called by muse, mutect2, varscan2
- ABCA12 | c.1211G>A p.R404Q (on ENST00000272895 / NM_173076.3; = p.R86Q on NM_015657.3) | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs752328328, COSV55961290, COSV99789386; called by muse, mutect2, varscan2
- ABCB1 | c.1402G>A p.E468K | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV55946143; called by muse, mutect2, varscan2
- ABCC12 | c.1858G>A p.D620N | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated (0.94); PolyPhen benign (0.034); catalogued as rs771670747, COSV60914554; called by muse, mutect2, varscan2
- ABCC8 | c.326C>T p.P109L | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV100217737; called by muse, varscan2
- ACAD10 | c.1913C>T p.S638F | Missense Mutation (SNP) | VAF 40/110 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.048); catalogued as COSV100564268; called by muse, mutect2, varscan2
- ACKR2 | c.678G>A p.M226I | Missense Mutation (SNP) | VAF 60/123 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV56180581; called by muse, mutect2, varscan2
- ACOX2 | c.1415C>T p.P472L | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.045); catalogued as COSV100250304; called by muse, mutect2, varscan2
- ACOXL | c.257A>G p.Y86C | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.593); catalogued as COSV100490656, COSV61328001; called by muse, mutect2, varscan2
- ACSM1 | c.398G>A p.R133Q | Missense Mutation (SNP) | VAF 31/48 reads (65%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs769122330, COSV54632818; called by muse, varscan2
- ACVRL1 | c.724G>A p.E242K | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66359752; called by muse, mutect2, varscan2
- ADA | c.157G>C p.D53H | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as COSV100866645, COSV65739954; called by muse, mutect2, varscan2
- ADAD1 | c.833G>A p.R278K | Missense Mutation (SNP) | VAF 37/48 reads (77%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56641700, COSV99635256, COSV99636304; called by muse, mutect2, varscan2
- ADAM22 | c.1387C>T p.P463S | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as COSV99718373; called by muse, mutect2, varscan2
- ADAM22 | c.1388C>T p.P463L | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as rs372937043; called by muse, mutect2, varscan2
- ADAMTS12 | c.4561C>T p.P1521S | Missense Mutation (SNP) | VAF 46/88 reads (52%) | SIFT tolerated (0.35); PolyPhen benign (0.018); catalogued as COSV61256925, COSV61257064; called by muse, mutect2, varscan2
- ADAMTS4 | c.1144G>A p.G382R | Missense Mutation (SNP) | VAF 38/108 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.119); catalogued as COSV100917573; called by muse, mutect2, varscan2
- ADAMTS6 | c.1471C>T p.R491C | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV66860100; called by muse, mutect2
- ADAMTS7 | c.3679C>T p.R1227* | Nonsense Mutation (SNP) | VAF 10/44 reads (23%) | catalogued as rs150520631; called by muse, mutect2, varscan2
- ADCY2 | c.1468G>A p.A490T | Missense Mutation (SNP) | VAF 29/40 reads (73%) | SIFT deleterious (0.03); PolyPhen benign (0.049); catalogued as COSV100604179, COSV57862658; called by muse, mutect2, varscan2
- ADCY8 | c.1246C>T p.L416F | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53895961, COSV99654440; called by muse, mutect2, varscan2
- ADGRF2 | c.985G>A p.E329K (on ENST00000296862 / NM_001368115.2; = p.E261K on NM_153839.7) | Missense Mutation (SNP) | VAF 28/128 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.786); catalogued as rs764110566, COSV57286334; called by muse, mutect2, varscan2
- ADGRV1 | c.622C>A p.P208T | Missense Mutation (SNP) | VAF 18/20 reads (90%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.705); catalogued as rs775156018, COSV101316537, COSV67977494; called by muse, mutect2, varscan2
- ADGRV1 | c.6493G>A p.E2165K | Missense Mutation (SNP) | VAF 9/10 reads (90%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV101316538; called by muse, mutect2, varscan2
- AFF2 | c.2935G>A p.A979T | Missense Mutation (SNP) | VAF 60/158 reads (38%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV99666375; called by muse, mutect2, varscan2
- AFF2 | c.3870G>A p.M1290I | Missense Mutation (SNP) | VAF 72/177 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.695); catalogued as COSV99666379; called by muse, mutect2, varscan2
- AFTPH | c.1965T>G p.I655M | Missense Mutation (SNP) | VAF 85/137 reads (62%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV99481239; called by muse, mutect2, varscan2
- AGBL1 | c.2375G>A p.R792Q | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.761); catalogued as COSV101224274; called by muse, mutect2, varscan2
- AHNAK | c.10267A>G p.N3423D | Missense Mutation (SNP) | VAF 60/125 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV99949682; called by muse, mutect2, varscan2
- AHR | c.104C>T p.P35L | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs868251284, COSV99620266; called by muse, mutect2, varscan2
- AKAP1 | c.1495C>T p.P499S | Missense Mutation (SNP) | VAF 46/120 reads (38%) | SIFT tolerated (0.83); PolyPhen benign (0.007); catalogued as COSV100028260; called by muse, mutect2, varscan2
- AL592490.1 | c.302C>T p.P101L | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as COSV69426434; called by muse, mutect2, varscan2
- AL592490.1 | c.301C>T p.P101S | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.001); catalogued as COSV101308289; called by muse, mutect2, varscan2
- AMBN | c.1069C>T p.P357S | Missense Mutation (SNP) | VAF 13/18 reads (72%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.762); catalogued as rs757573332, COSV100534499; called by muse, mutect2, varscan2
- AMER2 | c.1918C>T p.P640S | Missense Mutation (SNP) | VAF 40/90 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100766310; called by muse, mutect2, varscan2
- ANGEL2 | c.889C>T p.P297S | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT tolerated (0.69); PolyPhen benign (0.043); catalogued as COSV100853999; called by muse, mutect2, varscan2
- ANK3 | c.10165G>A p.D3389N | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.949); catalogued as rs763790019, COSV99782444; called by muse, mutect2, varscan2
- ANK3 | c.9601C>T p.P3201S | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.186); catalogued as rs750699498, COSV99782446; called by muse, mutect2, varscan2
- ANKK1 | c.229A>C p.K77Q | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.833); catalogued as COSV100393090; called by muse, mutect2, varscan2
- ANKRD30A | c.1183A>T p.I395F (on ENST00000611781; = p.I339F on NM_052997.2) | Missense Mutation (SNP) | VAF 31/56 reads (55%) | SIFT deleterious (0.03); PolyPhen benign (0.227); catalogued as COSV100654464; called by muse, mutect2, varscan2
- ANKRD35 | c.1817G>A p.G606E | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs781786302, COSV100841860; called by muse, mutect2, varscan2
- ANOS1 | c.996G>A p.W332* | Nonsense Mutation (SNP) | VAF 14/35 reads (40%) | catalogued as COSV52926812; called by muse, mutect2, varscan2
- ANXA13 | c.71A>G p.N24S | Missense Mutation (SNP) | VAF 43/127 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.161); catalogued as rs921531552, COSV99147073; called by muse, mutect2, varscan2
- ANXA8 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 51/243 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs1234169612; called by muse, mutect2, varscan2
- AOAH | c.1307-1G>A p.X436_splice | Splice Site (SNP) | VAF 7/43 reads (16%) | catalogued as COSV99333869; called by muse, mutect2, varscan2
- AOAH | c.399G>A p.W133* | Nonsense Mutation (SNP) | VAF 26/47 reads (55%) | catalogued as COSV51750686; called by muse, mutect2, varscan2
- AOC1 | c.2120C>T p.S707F | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV62871244; called by muse, mutect2, varscan2
- AOC3 | c.1441C>T p.P481S | Missense Mutation (SNP) | VAF 44/106 reads (42%) | SIFT tolerated (0.26); PolyPhen benign (0.039); catalogued as COSV99520415; called by muse, mutect2, varscan2
- APBB1IP | c.1469C>T p.S490L | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs762052919, COSV100882264; called by muse, mutect2
- APOB | c.10991C>T p.S3664F | Missense Mutation (SNP) | VAF 37/67 reads (55%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.952); catalogued as COSV99268191; called by muse, mutect2, varscan2
- APOB | c.9851C>T p.S3284F | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.212); catalogued as COSV51951697; called by muse, mutect2, varscan2
- APOO | c.481G>A p.V161I | Missense Mutation (SNP) | VAF 65/174 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as COSV101004912; called by muse, mutect2, varscan2
- APOO | c.481-1G>A p.X161_splice | Splice Site (SNP) | VAF 64/172 reads (37%) | catalogued as COSV101004913; called by muse, mutect2, varscan2
- AQR | c.358C>T p.P120S | Missense Mutation (SNP) | VAF 80/183 reads (44%) | SIFT tolerated (0.29); PolyPhen benign (0.031); catalogued as rs780893253, COSV99334731; called by muse, mutect2, varscan2
- ARGFX | c.706C>T p.L236F | Missense Mutation (SNP) | VAF 48/91 reads (53%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100544226, COSV57681617; called by muse, mutect2, varscan2
- ARHGAP29 | c.2882G>A p.G961E | Missense Mutation (SNP) | VAF 39/54 reads (72%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs867918256, COSV53110801; called by muse, mutect2, varscan2
- ARHGAP32 | c.4217C>T p.P1406L (on ENST00000310343 / NM_001378025.1; = p.P1057L on NM_014715.4) | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); catalogued as COSV100089371; called by muse, mutect2, varscan2
- ARHGAP39 | c.910C>T p.P304S | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99432292; called by muse, mutect2, varscan2
- ARHGAP6 | c.2173A>C p.K725Q | Missense Mutation (SNP) | VAF 103/271 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.09); catalogued as COSV100273583; called by muse, mutect2, varscan2
- ARMC2 | c.1169A>G p.N390S | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.368); catalogued as COSV100933663; called by muse, mutect2, varscan2
- ARMC2 | c.1786C>T p.P596S | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.81); PolyPhen benign (0.014); catalogued as COSV100933664; called by muse, mutect2, varscan2
- ARRDC5 | c.11G>A p.R4K | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs765510781, COSV67788299; called by muse, mutect2, varscan2
- ASB3 | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 30/58 reads (52%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV99712531; called by muse, mutect2, varscan2
- ATOH8 | c.196C>G p.R66G | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.184); catalogued as COSV100092876; called by muse, mutect2, varscan2
- ATP13A5 | c.2996C>T p.P999L | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.613); catalogued as COSV100665749; called by muse, mutect2, varscan2
- ATP1B4 | c.40C>T p.P14S | Missense Mutation (SNP) | VAF 102/228 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.063); catalogued as COSV54312159; called by muse, mutect2, varscan2
- ATP1B4 | c.64G>A p.D22N | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.38); catalogued as COSV99486571; called by muse, mutect2, varscan2
- ATP2B3 | c.1885G>A p.D629N | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as rs144964812, COSV54846177; called by muse, mutect2, varscan2
- ATP2C2 | c.1732C>T p.P578S | Missense Mutation (SNP) | VAF 50/90 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV99298645; called by muse, mutect2, varscan2
- ATRX | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 136/320 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV100969637; called by muse, mutect2, varscan2
- AWAT1 | c.665A>T p.E222V | Missense Mutation (SNP) | VAF 53/134 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100997234; called by muse, mutect2, varscan2
- AZGP1 | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 30/168 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99448227; called by muse, mutect2, varscan2
- BCLAF1 | c.232A>T p.R78* | Nonsense Mutation (SNP) | VAF 26/54 reads (48%) | catalogued as COSV100787039; called by muse, mutect2, varscan2
- BCLAF3 | c.916G>A p.E306K | Missense Mutation (SNP) | VAF 63/154 reads (41%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.575); catalogued as COSV100503407; called by muse, mutect2, varscan2
- BEX1 | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 100/272 reads (37%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV101022512; called by muse, varscan2
- BGN | c.584T>G p.L195R | Missense Mutation (SNP) | VAF 42/112 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100525287; called by muse, mutect2, varscan2
- BICC1 | c.1057C>T p.P353S | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54063785; called by muse, mutect2, varscan2
- BMP10 | c.488G>T p.R163L | Missense Mutation (SNP) | VAF 37/54 reads (69%) | SIFT tolerated (0.17); PolyPhen benign (0.326); catalogued as rs779454423, COSV54894444, COSV99770624; called by muse, mutect2, varscan2
- BOLL | c.100C>T p.R34C | Missense Mutation (SNP) | VAF 73/136 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs377264153; called by muse, mutect2, varscan2
- BRAF | c.1520C>T p.S507L (on ENST00000288602 / NM_001374244.1; = p.S467L on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.547); catalogued as rs867748453, COSV56106484; called by muse, mutect2, varscan2
- BRCA2 | c.5626G>A p.E1876K | Missense Mutation (SNP) | VAF 35/77 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0.209); catalogued as rs397507793, CM960193, COSV66461924; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRD8 | c.3180G>A p.M1060I | Missense Mutation (SNP) | VAF 27/41 reads (66%) | SIFT tolerated (0.19); PolyPhen benign (0.01); catalogued as COSV99649133; called by muse, mutect2, varscan2
- BRINP2 | c.1253G>A p.W418* | Nonsense Mutation (SNP) | VAF 36/78 reads (46%) | catalogued as COSV64177404; called by muse, mutect2, varscan2
- BUB1B | c.2066C>T p.S689F | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV99807325; called by muse, mutect2, varscan2
- C10orf120 | c.779G>A p.G260E | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.069); catalogued as COSV100271783; called by muse, mutect2, varscan2
- C11orf40 | n.142G>A | Splice Region (SNP) | VAF 12/41 reads (29%) | catalogued as COSV56890552; called by muse, mutect2, varscan2
- C16orf89 | c.920C>T p.S307L | Missense Mutation (SNP) | VAF 38/71 reads (54%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1301302453, COSV60122446; called by muse, mutect2, varscan2
- C1S | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 42/106 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.579); catalogued as COSV61072077; called by muse, mutect2, varscan2
- C2orf16 | c.739G>A p.D247N | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.546); catalogued as COSV101284430; called by muse, mutect2, varscan2
- C3orf20 | c.1726G>A p.E576K | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.52); catalogued as COSV53782507; called by muse, mutect2, varscan2
- C6 | c.2678A>T p.N893I | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV99667818; called by muse, mutect2, varscan2
- C7orf25 | c.1018C>T p.Q340* | Nonsense Mutation (SNP) | VAF 39/75 reads (52%) | catalogued as COSV100623672; called by muse, mutect2, varscan2
- CA10 | c.28C>T p.L10F | Missense Mutation (SNP) | VAF 39/94 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.047); catalogued as COSV99565212; called by muse, mutect2, varscan2
- CACNA1E | c.5981G>A p.G1994E | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.322); catalogued as COSV62396984; called by muse, mutect2, varscan2
- CACNA1F | c.5908G>A p.E1970K | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as rs371796154, COSV54294411, COSV99603155; called by muse, mutect2, varscan2
- CADM3 | c.494G>A p.W165* (on ENST00000368125 / NM_001127173.3; = p.W199* on NM_021189.5) | Nonsense Mutation (SNP) | VAF 19/52 reads (37%) | catalogued as COSV100930417; called by muse, mutect2, varscan2
- CADPS2 | c.1324G>A p.E442K | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100466029; called by muse, mutect2, varscan2
- CAMKK1 | c.745G>A p.E249K | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs761829053, COSV99340586; called by muse, mutect2, varscan2
- CAMSAP3 | c.826T>C p.F276L | Missense Mutation (SNP) | VAF 76/194 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV99352028; called by muse, mutect2, varscan2
- CAPZA3 | c.407G>A p.G136E | Missense Mutation (SNP) | VAF 38/74 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs868744411, COSV56849081, COSV56850605; called by muse, mutect2, varscan2
- CARD11 | c.1162G>A p.E388K | Missense Mutation (SNP) | VAF 49/99 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.277); catalogued as COSV101210974; called by muse, mutect2, varscan2
- CARMIL2 | c.1450G>A p.D484N | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.023); catalogued as COSV100576317; called by muse, mutect2, varscan2
- CASZ1 | c.539C>T p.S180F | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.568); catalogued as COSV100682195; called by muse, mutect2, varscan2
- CATSPERB | c.601G>A p.D201N | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs765427457, COSV99831798; called by muse, mutect2, varscan2
- CBLL2 | c.676G>A p.E226K | Missense Mutation (SNP) | VAF 50/115 reads (43%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.619); catalogued as COSV60368825; called by muse, mutect2, varscan2
- CCBE1 | c.1060G>A p.E354K | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.024); catalogued as COSV67949165; called by muse, mutect2, varscan2
- CCDC144A | c.829G>A p.E277K | Missense Mutation (SNP) | VAF 34/97 reads (35%) | SIFT tolerated (0.5); PolyPhen benign (0.134); catalogued as COSV60698907; called by muse, mutect2, varscan2
- CCDC172 | c.693G>A p.M231I | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as COSV60936518; called by muse, mutect2, varscan2
- CCNB3 | c.2030C>T p.S677L | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.966); catalogued as COSV99329927; called by muse, mutect2, varscan2
- CCR1 | c.22G>A p.E8K | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV56121983; called by muse, mutect2, varscan2
- CD109 | c.997G>A p.G333S | Missense Mutation (SNP) | VAF 53/111 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as rs751693579, COSV99754656; called by muse, mutect2, varscan2
- CD163 | c.2335G>A p.G779R | Missense Mutation (SNP) | VAF 78/214 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100776148; called by muse, mutect2, varscan2
- CD209 | c.190C>T p.P64S | Missense Mutation (SNP) | VAF 43/109 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs1187029789, COSV99214453; called by muse, mutect2, varscan2
- CD99L2 | c.352G>A p.D118N | Missense Mutation (SNP) | VAF 62/135 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.237); catalogued as rs201144465, COSV60936211; called by muse, mutect2, varscan2
- CDC37 | c.409G>A p.E137K | Missense Mutation (SNP) | VAF 105/271 reads (39%) | SIFT tolerated (0.33); PolyPhen benign (0.393); catalogued as COSV99705900; called by muse, mutect2, varscan2
- CDC42BPG | c.3980C>T p.P1327L | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs776309492, COSV100712164; called by muse, mutect2, varscan2
- CDH12 | c.416C>T p.P139L | Missense Mutation (SNP) | VAF 37/73 reads (51%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); catalogued as rs1292742039, COSV101203360; called by muse, mutect2, varscan2
- CDH2 | c.1306G>A p.D436N | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as rs142861371, COSV52274288; called by muse, mutect2, varscan2
- CDH4 | c.105C>G p.F35L | Missense Mutation (SNP) | VAF 112/202 reads (55%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.966); catalogued as COSV100849680; called by muse, mutect2, varscan2
- CDH5 | c.1765G>A p.D589N | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT tolerated (0.23); PolyPhen benign (0.048); catalogued as rs1487915054, COSV100439453; called by muse, mutect2, varscan2
- CDH9 | c.967G>A p.D323N | Missense Mutation (SNP) | VAF 31/117 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as COSV50328845, COSV99155952; called by muse, mutect2, varscan2
- CDKN2A | c.165dup p.S56Qfs*64 | Frame Shift Ins (INS) | VAF 8/12 reads (67%) | catalogued as COSV58729383; called by mutect2, varscan2
- CECR2 | c.2735C>T p.S912F (on ENST00000342247 / NM_001290047.2; = p.S729F on NM_001290046.1) | Missense Mutation (SNP) | VAF 37/55 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99379144; called by muse, mutect2, varscan2
- CELA2B | c.356G>A p.G119E | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV101025883; called by muse, mutect2, varscan2
- CENPF | c.1169A>G p.K390R | Missense Mutation (SNP) | VAF 41/97 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.422); catalogued as COSV100871995; called by muse, mutect2, varscan2
- CEP128 | c.2347C>T p.Q783* | Nonsense Mutation (SNP) | VAF 15/54 reads (28%) | catalogued as COSV55374856; called by muse, mutect2
- CFAP300 | c.362G>A p.R121Q | Missense Mutation (SNP) | VAF 40/134 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs1420836171, COSV71570996; called by muse, mutect2, varscan2
- CFAP52 | c.946C>T p.R316C | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.017); catalogued as rs1361072712, COSV55343747; called by muse, mutect2, varscan2
- CFHR5 | c.1603G>A p.D535N | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as rs748341345, COSV56818591; called by muse, mutect2, varscan2
- CHAT | c.676C>T p.P226S | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.74); PolyPhen benign (0.014); catalogued as COSV100340925; called by muse, mutect2, varscan2
- CHPF2 | c.406G>A p.G136R | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); catalogued as COSV99223355; called by muse, mutect2, varscan2
- CHPF2 | c.407G>T p.G136V | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99223356; called by muse, mutect2, varscan2
- CHRM2 | c.826C>T p.Q276* | Nonsense Mutation (SNP) | VAF 12/40 reads (30%) | catalogued as COSV57768724; called by muse, varscan2
- CHRM2 | c.863C>T p.S288L | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.285); catalogued as COSV57780363; called by muse, varscan2
- CHRM3 | c.564G>A p.M188I | Missense Mutation (SNP) | VAF 62/157 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV55087950, COSV99699512; called by muse, mutect2, varscan2
- CHRM3 | c.832G>A p.E278K | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.77); PolyPhen benign (0.015); catalogued as rs751770776, COSV99699514; called by muse, mutect2, varscan2
- CHRM3 | c.1312G>A p.A438T | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as COSV55104687; called by muse, mutect2, varscan2
- CHRNB3 | c.415G>A p.G139R | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1171439455, COSV99251519; called by muse, mutect2, varscan2
- CHRNB3 | c.416G>A p.G139E | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs900331287, COSV99251521; called by muse, mutect2, varscan2
- CILK1 | c.502C>T p.P168S | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV100608045; called by muse, mutect2, varscan2
- CKM | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 33/49 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1267054691, COSV99488885; called by muse, mutect2, varscan2
- CLCN1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 21/38 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.838); catalogued as COSV100578549, COSV58372214; called by muse, mutect2, varscan2
- CLCN1 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV100578551; called by muse, mutect2, varscan2
- CLEC10A | c.848C>T p.A283V (on ENST00000254868 / NM_182906.4; = p.A259V on NM_006344.4) | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.397); catalogued as COSV99644939; called by muse, mutect2, varscan2
- CLIP1 | c.1670A>G p.E557G (on ENST00000620786 / NM_001247997.1; = p.E546G on NM_002956.2) | Missense Mutation (SNP) | VAF 24/323 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.816); catalogued as COSV100212411; called by muse, mutect2
- CLSTN2 | c.1462C>T p.P488S | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.175); catalogued as COSV101515933; called by muse, mutect2, varscan2
- CLTCL1 | c.3686C>T p.S1229F | Missense Mutation (SNP) | VAF 19/29 reads (66%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.952); catalogued as COSV99595904; called by muse, mutect2, varscan2
- CLVS1 | c.631G>A p.D211N | Missense Mutation (SNP) | VAF 103/198 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.224); catalogued as COSV57975913; called by muse, mutect2, varscan2
- CNGA3 | c.1354G>A p.D452N | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT tolerated (0.12); PolyPhen benign (0.301); catalogued as rs781348502, COSV99737542; called by muse, mutect2, varscan2
- CNTN1 | c.1192G>A p.G398R | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100751917; called by muse, mutect2, varscan2
- CNTN1 | c.1303G>A p.E435K | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.302); catalogued as rs568941586, COSV100751918; called by muse, mutect2, varscan2
- CNTNAP2 | c.3125C>T p.S1042F | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT tolerated (0.74); PolyPhen benign (0.038); catalogued as COSV100673085; called by muse, mutect2, varscan2
- CNTNAP5 | c.1186C>T p.R396* | Nonsense Mutation (SNP) | VAF 43/76 reads (57%) | catalogued as rs1447158750, COSV70472787; called by muse, mutect2, varscan2
- CNTNAP5 | c.1819G>A p.D607N | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1336167069, COSV70482138, COSV70488622; called by muse, mutect2, varscan2
- COBLL1 | c.1009C>T p.P337S (on ENST00000392717; = p.P299S on NM_014900.5) | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99528706; called by muse, mutect2, varscan2
- COL2A1 | c.2017C>T p.P673S | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV100477541; called by muse, mutect2, varscan2
- COL4A4 | c.3361G>A p.G1121R | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100307742; called by muse, mutect2, varscan2
- COL6A2 | c.2065G>A p.E689K | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.908); catalogued as rs560146338, COSV100154300; called by muse, mutect2, varscan2
- COL6A6 | c.5104C>T p.L1702F | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV100650969; called by muse, mutect2
- COL7A1 | c.6725G>A p.G2242E | Missense Mutation (SNP) | VAF 22/156 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM992854, COSV100097769; called by muse, mutect2, varscan2
- COL8A1 | c.613C>T p.P205S | Missense Mutation (SNP) | VAF 25/37 reads (68%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.672); catalogued as COSV53745102; called by muse, mutect2, varscan2
- COL9A1 | c.1393C>T p.P465S | Missense Mutation (SNP) | VAF 20/33 reads (61%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); catalogued as COSV57895958; called by muse, mutect2, varscan2
- CORIN | c.2198G>A p.G733E | Missense Mutation (SNP) | VAF 35/57 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1183115819, COSV99904479; called by muse, mutect2, varscan2
- CORIN | c.1834G>A p.E612K | Missense Mutation (SNP) | VAF 33/42 reads (79%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.664); catalogued as COSV56694321; called by muse, mutect2, varscan2
- CPM | c.884C>T p.S295F | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as COSV100615279; called by muse, mutect2, varscan2
- CPNE4 | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV101456817; called by muse, varscan2
- CPS1 | c.2002C>T p.P668S | Missense Mutation (SNP) | VAF 36/68 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51801524; called by muse, mutect2, varscan2
- CR1 | c.5791G>A p.G1931R | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as COSV100888056, COSV65455508; called by muse, mutect2, varscan2
- CRB1 | c.2029G>A p.E677K | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0.062); catalogued as rs867230786, COSV66334082; called by muse, mutect2, varscan2
- CRB1 | c.4193C>T p.P1398L | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.058); catalogued as COSV100959486; called by muse, mutect2, varscan2
- CRYGC | c.146C>T p.P49L | Missense Mutation (SNP) | VAF 50/106 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99965398; called by muse, mutect2, varscan2
- CSE1L | c.2566A>G p.M856V | Missense Mutation (SNP) | VAF 32/131 reads (24%) | SIFT tolerated (0.37); PolyPhen benign (0.037); catalogued as COSV99522279; called by muse, mutect2, varscan2
- CSF1 | c.1217C>T p.S406L | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as COSV100294830; called by muse, mutect2, varscan2
- CSH1 | c.463G>A p.E155K | Missense Mutation (SNP) | VAF 68/169 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.091); catalogued as COSV100298457; called by muse, mutect2, varscan2
- CSMD1 | c.8024G>A p.R2675Q (on ENST00000520002; = p.R2674Q on NM_033225.6) | Missense Mutation (SNP) | VAF 86/258 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.027); catalogued as rs775089714, COSV100153884, COSV59332663; called by muse, mutect2, varscan2
- CSMD1 | c.6250G>A p.E2084K (on ENST00000520002; = p.E2083K on NM_033225.6) | Missense Mutation (SNP) | VAF 50/102 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.151); catalogued as COSV59334123; called by muse, mutect2, varscan2
- CSMD2 | c.7853C>T p.A2618V | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.909); catalogued as COSV53946654, COSV99595562; called by muse, mutect2, varscan2
- CSMD2 | c.7469C>T p.S2490F | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.222); catalogued as COSV99595564; called by muse, mutect2, varscan2
- CSMD2 | c.3494G>A p.G1165E | Missense Mutation (SNP) | VAF 33/54 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53883818; called by muse, varscan2
- CSMD2 | c.2482C>T p.P828S | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1256151793, COSV53879518, COSV99596900; called by muse, mutect2, varscan2
- CSMD3 | c.9443C>T p.S3148F (on ENST00000297405 / NM_001363185.1; = p.S2979F on NM_052900.3) | Missense Mutation (SNP) | VAF 35/115 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as COSV99831656, COSV99848213; called by muse, mutect2, varscan2
- CSMD3 | c.1612G>A p.D538N (on ENST00000297405 / NM_001363185.1; = p.D434N on NM_052900.3) | Missense Mutation (SNP) | VAF 48/100 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52252722, COSV99847716; called by muse, mutect2, varscan2
- CSTF3 | c.1421G>A p.G474E | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.24); catalogued as COSV100124352; called by muse, mutect2, varscan2
- CTNNBL1 | c.947C>T p.S316F | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as COSV63747309; called by muse, mutect2, varscan2
- CTNND1 | c.1928C>T p.T643I (on ENST00000399050 / NM_001085458.2; = p.T637I on NM_001331.3) | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV100650300; called by muse, mutect2, varscan2
- CTSH | c.699C>T p.I233= | Splice Region (SNP) | VAF 28/80 reads (35%) | catalogued as rs144589404; called by muse, mutect2, varscan2
- CUX2 | c.4270C>T p.P1424S | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0.003); catalogued as COSV55648302, COSV99920809; called by muse, mutect2, varscan2
- CWF19L2 | c.2324A>G p.K775R | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.52); PolyPhen benign (0.013); catalogued as COSV99979931; called by muse, varscan2
- CWF19L2 | c.2314C>T p.P772S | Missense Mutation (SNP) | VAF 30/50 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56521599; called by muse, varscan2
- CWH43 | c.772C>T p.R258C | Missense Mutation (SNP) | VAF 37/49 reads (76%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs762343467, COSV56936664, COSV56939862; called by muse, mutect2, varscan2
- CYP2C18 | c.1288G>A p.A430T | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT tolerated (0.34); PolyPhen benign (0.088); catalogued as rs1482298087, COSV53670803; called by muse, mutect2, varscan2
- CYP2J2 | c.892G>A p.E298K | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.314); catalogued as COSV64607247; called by muse, mutect2, varscan2
- DAB1 | c.1042C>T p.P348S (on ENST00000371231; = p.P315S on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0.23); catalogued as COSV100976668; called by muse, mutect2, varscan2
- DAZAP1 | c.764C>T p.A255V | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as COSV99245498; called by muse, mutect2, varscan2
- DDR1 | c.2245C>T p.Q749* (on ENST00000324771; = p.Q712* on NM_001954.4) | Nonsense Mutation (SNP) | VAF 11/17 reads (65%) | catalogued as COSV61321276; called by muse, mutect2, varscan2
- DEFB125 | c.211C>T p.P71S | Missense Mutation (SNP) | VAF 90/131 reads (69%) | SIFT deleterious (0.04); PolyPhen benign (0.161); catalogued as COSV66703111; called by muse, mutect2, varscan2
- DEPDC1B | c.1445C>T p.P482L | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99409892; called by muse, mutect2
- DIAPH3 | c.3542C>T p.P1181L | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.922); catalogued as rs781283166, COSV100930786; called by muse, mutect2, varscan2
- DICER1 | c.2194G>T p.E732* | Nonsense Mutation (SNP) | VAF 36/130 reads (28%) | catalogued as COSV100602567; called by muse, mutect2, varscan2
- DLG2 | c.2491G>A p.G831R | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.542); catalogued as COSV99719826; called by muse, mutect2, varscan2
- DMBT1 | c.5584G>A p.E1862K (on ENST00000338354 / NM_001377530.1; = p.E1105K on NM_004406.3) | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.803); catalogued as rs1045906158, COSV57534249; called by muse, mutect2, varscan2
- DNAH1 | c.10006G>A p.E3336K | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs748670005, COSV70238876; called by muse, mutect2, varscan2
- DNAH10 | c.9540G>A p.M3180I (on ENST00000409039; = p.M3119I on NM_207437.3) | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV101292778; called by muse, mutect2, varscan2
- DNAH2 | c.9350G>A p.G3117E | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV101209594; called by muse, mutect2, varscan2
- DNAH3 | c.6379C>T p.L2127F | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.701); catalogued as COSV99770730; called by muse, mutect2, varscan2
- DNAH7 | c.3652G>A p.D1218N | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99044788; called by muse, mutect2, varscan2
- DNAH8 | c.8621C>T p.T2874I | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV100547265; called by muse, mutect2, varscan2
- DNMT1 | c.3317C>T p.P1106L | Missense Mutation (SNP) | VAF 61/138 reads (44%) | SIFT tolerated (0.49); PolyPhen benign (0.012); catalogued as COSV100533081; called by muse, mutect2, varscan2
- DOCK11 | c.224C>T p.S75L | Missense Mutation (SNP) | VAF 43/111 reads (39%) | SIFT tolerated (0.21); PolyPhen benign (0.013); catalogued as rs765984589, COSV99353326; called by muse, mutect2
- DOCK2 | c.3956G>A p.S1319N | Missense Mutation (SNP) | VAF 21/30 reads (70%) | SIFT deleterious (0); PolyPhen benign (0.083); catalogued as COSV56954898, COSV56995863; called by muse, mutect2, varscan2
- DOCK3 | c.3148C>T p.Q1050* | Nonsense Mutation (SNP) | VAF 12/22 reads (55%) | catalogued as COSV99815196; called by muse, mutect2, varscan2
- DOCK4 | c.5102C>T p.P1701L | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV101447987; called by muse, mutect2, varscan2
- DOK5 | c.169C>T p.H57Y | Missense Mutation (SNP) | VAF 34/67 reads (51%) | SIFT tolerated (0.68); PolyPhen probably damaging (0.932); catalogued as COSV52817022; called by muse, mutect2, varscan2
- DPH2 | c.1042C>T p.P348S | Missense Mutation (SNP) | VAF 49/91 reads (54%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as rs755936243, COSV52542832; called by muse, mutect2, varscan2
- DPYSL5 | c.164G>A p.G55E | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs776793161, COSV56509191; called by muse, mutect2, varscan2
- DQX1 | c.476G>A p.R159Q | Missense Mutation (SNP) | VAF 48/84 reads (57%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.543); catalogued as rs766343104, COSV101099248; called by muse, mutect2, varscan2
- DSC3 | c.1390G>A p.D464N | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.4); PolyPhen benign (0.162); catalogued as COSV64572766; called by muse, mutect2, varscan2
- DSCAM | c.5383G>A p.D1795N | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV68037613; called by muse, mutect2, varscan2
- DSG2 | c.1336G>A p.E446K | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55197495; called by muse, mutect2, varscan2
- DSG3 | c.266G>A p.G89E | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57128316; called by muse, mutect2, varscan2
- DSG4 | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV57390641; called by muse, mutect2, varscan2
- DSPP | c.1273G>A p.G425R | Missense Mutation (SNP) | VAF 24/37 reads (65%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.068); catalogued as rs1260796476, COSV99218011; called by muse, mutect2, varscan2
- DSPP | c.1274G>A p.G425E | Missense Mutation (SNP) | VAF 25/38 reads (66%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.076); catalogued as COSV99217587, COSV99218012; called by muse, mutect2, varscan2
- EFCAB6 | c.2983G>A p.E995K | Missense Mutation (SNP) | VAF 43/63 reads (68%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.655); catalogued as COSV99412337, COSV99414448; called by muse, mutect2, varscan2
- EFCAB7 | c.211C>T p.P71S | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1053414477, COSV64314524; called by muse, mutect2, varscan2
- EFR3A | c.1489C>T p.R497* | Nonsense Mutation (SNP) | VAF 53/110 reads (48%) | catalogued as rs752611506, COSV54454006; called by muse, mutect2, varscan2
- EGR3 | c.1142C>T p.P381L | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.19); catalogued as COSV100416289; called by muse, mutect2, varscan2
- EIF2AK1 | c.554G>A p.R185K | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.057); catalogued as COSV99552354; called by muse, mutect2, varscan2
- EIF2D | c.268C>T p.P90S | Missense Mutation (SNP) | VAF 39/71 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV99663066; called by muse, mutect2, varscan2
- EIF2S1 | c.698C>T p.P233L | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99371971; called by muse, mutect2, varscan2
- ELAVL2 | c.338C>T p.S113F | Missense Mutation (SNP) | VAF 26/38 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV56357819; called by muse, mutect2, varscan2
- ELF4 | c.1772C>T p.P591L | Missense Mutation (SNP) | VAF 75/188 reads (40%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs755967068, COSV100257605; called by muse, mutect2, varscan2
- ELMO1 | c.512T>G p.V171G | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100166119; called by muse, mutect2, varscan2
- ELOVL4 | c.938G>A p.G313E | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.417); catalogued as COSV100876420; called by muse, mutect2, varscan2
- ELP3 | c.931C>T p.R311C | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.677); catalogued as rs775947064, COSV56457551; called by muse, mutect2, varscan2
- EML1 | c.1654C>T p.H552Y | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99215659; called by muse, mutect2, varscan2
- ENG | c.391C>T p.P131S | Missense Mutation (SNP) | VAF 16/20 reads (80%) | SIFT tolerated (0.14); PolyPhen benign (0.323); catalogued as COSV100785348; called by muse, mutect2, varscan2
- ENPP1 | c.905A>G p.K302R | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.405); catalogued as COSV100719654; called by muse, mutect2, varscan2
- EPHA10 | c.425C>T p.P142L | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV60404522; called by muse, mutect2, varscan2
- EPHA7 | c.2684G>A p.R895Q | Missense Mutation (SNP) | VAF 54/113 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs754119070, COSV65179395; called by muse, mutect2, varscan2
- ERBB3 | c.3901C>T p.Q1301* | Nonsense Mutation (SNP) | VAF 60/157 reads (38%) | catalogued as COSV57262583, COSV99917930; called by muse, mutect2, varscan2
- ERBB4 | c.3857C>T p.S1286F | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.506); catalogued as rs1213182678, COSV100727912, COSV61499936; called by muse, mutect2, varscan2
- ERBB4 | c.2867-1G>A p.X956_splice | Splice Site (SNP) | VAF 28/57 reads (49%) | catalogued as COSV100726439, COSV61493101; called by muse, mutect2, varscan2
- ERC2 | c.698G>A p.R233Q | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.968); catalogued as rs747730160, COSV55605679; called by muse, mutect2
- ERC2 | c.76C>T p.R26C | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs780679678, COSV55628775; called by muse, mutect2, varscan2
- ERV3-1 | c.335C>T p.S112F | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.01); catalogued as rs777377220, COSV51427954; called by mutect2, varscan2
- ESRP1 | c.1259C>T p.P420L | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.979); catalogued as COSV100619668; called by muse, mutect2, varscan2
- ESS2 | c.746C>T p.T249M | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761230219, COSV52817133; called by muse, mutect2, varscan2
- EVI5 | c.1870G>A p.G624R | Missense Mutation (SNP) | VAF 23/28 reads (82%) | SIFT tolerated (0.13); PolyPhen benign (0.197); catalogued as COSV100945479; called by muse, mutect2, varscan2
- EYA1 | c.949C>T p.P317S | Missense Mutation (SNP) | VAF 68/184 reads (37%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); catalogued as COSV58176069; called by muse, mutect2, varscan2
- F8 | c.1798G>A p.E600K | Missense Mutation (SNP) | VAF 103/253 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as CM0911112, CM123900, CM990547, COSV100811991, COSV64270472; called by muse, mutect2, varscan2
- FAM135B | c.1970C>T p.S657F | Missense Mutation (SNP) | VAF 53/104 reads (51%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV52716564; called by muse, mutect2, varscan2
- FAM151A | c.577T>C p.F193L | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100157131; called by muse, mutect2, varscan2
- FAM160A2 | c.403G>C p.E135Q | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.896); catalogued as COSV56410343, COSV99792530; called by muse, mutect2, varscan2
- FAM171B | c.1951C>T p.Q651* | Nonsense Mutation (SNP) | VAF 44/92 reads (48%) | catalogued as COSV100489023; called by muse, mutect2, varscan2
- FAM47A | c.1009C>T p.L337F | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.999); catalogued as rs1441492553, COSV100650095, COSV100650099; called by muse, mutect2, varscan2
- FAM81B | c.871G>A p.E291K | Missense Mutation (SNP) | VAF 25/38 reads (66%) | SIFT tolerated (0.05); PolyPhen benign (0.069); catalogued as rs148381850, COSV51986553; called by muse, mutect2, varscan2
- FANCB | c.1367C>T p.S456F | Missense Mutation (SNP) | VAF 32/69 reads (46%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV100146698; called by muse, mutect2, varscan2
- FANCI | c.1597C>T p.R533* | Nonsense Mutation (SNP) | VAF 34/83 reads (41%) | catalogued as rs1347292940, COSV55527994; called by muse, mutect2, varscan2
- FAT4 | c.9619G>A p.E3207K | Missense Mutation (SNP) | VAF 56/79 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs868613088, COSV58715034; called by muse, mutect2, varscan2
- FBLIM1 | c.245A>G p.N82S | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.97); catalogued as rs375115514; called by muse, mutect2, varscan2
- FBN1 | c.1858C>T p.P620S | Missense Mutation (SNP) | VAF 37/93 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.1); catalogued as rs1220853793, COSV100356450; called by muse, mutect2, varscan2
- FBN3 | c.6160G>A p.E2054K | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.708); catalogued as rs149936210; called by muse, mutect2, varscan2
- FBXW4 | c.1146G>A p.W382* | Nonsense Mutation (SNP) | VAF 15/50 reads (30%) | catalogued as COSV58706587, COSV58708035; called by muse, mutect2, varscan2
- FCN2 | c.425G>A p.W142* | Nonsense Mutation (SNP) | VAF 9/11 reads (82%) | catalogued as COSV99391446; called by muse, mutect2, varscan2
- FCRL1 | c.477G>C p.K159N | Missense Mutation (SNP) | VAF 40/80 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100839908; called by muse, mutect2, varscan2
- FER1L6 | c.4040G>A p.G1347E | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101206211; called by muse, mutect2, varscan2
- FGD6 | c.3743G>A p.G1248E | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100676823; called by muse, mutect2, varscan2
- FGF7 | c.527G>A p.G176E | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51065513; called by muse, mutect2, varscan2
- FGFR4 | c.2081C>T p.P694L | Missense Mutation (SNP) | VAF 24/40 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52801894, COSV99449336; called by muse, mutect2, varscan2
- FIGNL1 | c.1438A>T p.K480* | Nonsense Mutation (SNP) | VAF 18/69 reads (26%) | catalogued as COSV100794963; called by muse, mutect2, varscan2
- FLG | c.5170G>A p.G1724R | Missense Mutation (SNP) | VAF 150/372 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV64240140; called by muse, mutect2, varscan2
- FLT1 | c.3118G>A p.D1040N | Missense Mutation (SNP) | VAF 47/108 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56717248; called by muse, mutect2, varscan2
- FLT4 | c.361G>A p.E121K | Missense Mutation (SNP) | VAF 19/29 reads (66%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as rs371804364; called by muse, mutect2, varscan2
- FMNL2 | c.2060G>A p.G687E | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.503); catalogued as COSV99980921; called by muse, mutect2, varscan2
- FRAS1 | c.6295G>A p.E2099K | Missense Mutation (SNP) | VAF 23/33 reads (70%) | SIFT tolerated (0.21); PolyPhen benign (0.11); catalogued as COSV53665020, COSV99355909; called by muse, mutect2, varscan2
- FREM1 | c.3808C>T p.P1270S | Missense Mutation (SNP) | VAF 30/44 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV101085513; called by muse, mutect2, varscan2
- FREM1 | c.3401A>T p.E1134V | Missense Mutation (SNP) | VAF 48/56 reads (86%) | SIFT deleterious (0.03); PolyPhen benign (0.231); catalogued as rs1290149846, COSV101085514; called by muse, mutect2, varscan2
- FRMPD1 | c.4151G>A p.R1384Q | Missense Mutation (SNP) | VAF 27/42 reads (64%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.84); catalogued as rs777791640, COSV66699619; called by muse, mutect2, varscan2
- FRMPD3 | c.2254C>T p.R752* | Nonsense Mutation (SNP) | VAF 24/75 reads (32%) | catalogued as COSV99346555, COSV99347309; called by muse, mutect2, varscan2
- GABRE | c.1346G>A p.W449* | Nonsense Mutation (SNP) | VAF 16/46 reads (35%) | catalogued as COSV100944385; called by muse, mutect2, varscan2
- GAD1 | c.1339G>A p.D447N | Missense Mutation (SNP) | VAF 38/68 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1432510263, COSV64025488; called by muse, mutect2, varscan2
- GBA3 | c.700C>T p.P234S | Missense Mutation (SNP) | VAF 41/63 reads (65%) | SIFT tolerated (0.11); PolyPhen benign (0.118); catalogued as COSV72437959; called by muse, mutect2, varscan2
- GBP6 | c.1034C>T p.P345L | Missense Mutation (SNP) | VAF 29/40 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1405738207, COSV100969701; called by muse, mutect2, varscan2
- GCM1 | c.78C>T p.N26= | Splice Region (SNP) | VAF 45/88 reads (51%) | catalogued as rs984489102, COSV52520833; called by muse, mutect2, varscan2
- GDAP1 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 112/213 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV55186490, COSV99619887; called by muse, mutect2, varscan2
- GJA8 | c.1153G>A p.E385K | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.775); catalogued as COSV99569723; called by muse, mutect2, varscan2
- GK2 | c.814G>A p.E272K | Missense Mutation (SNP) | VAF 73/100 reads (73%) | SIFT tolerated (0.88); PolyPhen benign (0.003); catalogued as COSV62626915; called by muse, mutect2, varscan2
- GPAT2 | c.1915G>A p.A639T | Missense Mutation (SNP) | VAF 27/47 reads (57%) | SIFT tolerated (0.19); PolyPhen benign (0.046); catalogued as COSV100853241, COSV100853359; called by muse, mutect2, varscan2
- GPAT3 | c.268G>A p.D90N | Missense Mutation (SNP) | VAF 44/69 reads (64%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs768699869, COSV100023303; called by muse, mutect2, varscan2
- GPC5 | c.1315G>A p.A439T | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.823); catalogued as COSV100996111; called by muse, mutect2, varscan2
- GPNMB | c.354G>T p.K118N | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.201); catalogued as COSV99326853; called by muse, mutect2, varscan2
- GPR179 | c.4204G>A p.D1402N (on ENST00000621958; = p.D1401N on NM_001004334.4) | Missense Mutation (SNP) | VAF 31/99 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.133); catalogued as rs553412018; called by muse, mutect2, varscan2
- GPR50 | c.733C>T p.L245F | Missense Mutation (SNP) | VAF 56/114 reads (49%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.573); catalogued as COSV99506693; called by muse, mutect2, varscan2
- GPRASP2 | c.970G>A p.D324N | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV100176958; called by muse, mutect2, varscan2
- GPRC6A | c.1382C>T p.S461L | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.338); catalogued as COSV100114804; called by muse, mutect2, varscan2
- GPRIN2 | c.1022C>T p.P341L | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.924); catalogued as COSV100966488; called by muse, mutect2
- GRIK2 | c.2525T>A p.F842Y | Missense Mutation (SNP) | VAF 48/105 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.048); catalogued as COSV100029506; called by muse, mutect2, varscan2
- GRIP2 | c.858G>A p.R286= (on ENST00000619221; = p.R189= on NM_001080423.4) | Splice Region (SNP) | VAF 7/10 reads (70%) | catalogued as COSV99817690; called by muse, mutect2, varscan2
- GRM4 | c.1003C>T p.L335F | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV100946899; called by muse, mutect2, varscan2
- GRM5 | c.334T>C p.F112L | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.985); catalogued as COSV100554588; called by muse, mutect2, varscan2
- GRXCR1 | c.742C>T p.L248F | Missense Mutation (SNP) | VAF 71/113 reads (63%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV67671083, COSV67673987; called by muse, mutect2, varscan2
- GTF3C1 | c.1289C>T p.S430F | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV62238905; called by muse, mutect2, varscan2
- H1-0 | c.394A>G p.K132E | Missense Mutation (SNP) | VAF 36/51 reads (71%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.968); catalogued as COSV50648701; called by muse, mutect2, varscan2
- H1-7 | c.721G>A p.E241K | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.421); catalogued as COSV100622267; called by muse, mutect2, varscan2
- H2AP | c.29C>T p.S10L | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.574); catalogued as rs748041446, COSV100586952; called by muse, mutect2, varscan2
- HBD | c.301C>T p.P101S | Missense Mutation (SNP) | VAF 38/101 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.905); catalogued as rs528751190, COSV53082024; called by muse, mutect2, varscan2
- HBG1 | c.262C>T p.Q88* | Nonsense Mutation (SNP) | VAF 17/28 reads (61%) | catalogued as COSV100400644, COSV100400703; called by muse, mutect2, varscan2
- HCAR1 | c.856C>T p.P286S | Missense Mutation (SNP) | VAF 71/175 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.063); catalogued as rs757909237, COSV63671357; called by muse, mutect2, varscan2
- HCAR1 | c.773G>A p.G258E | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV100811796; called by muse, mutect2, varscan2
- HCLS1 | c.256C>T p.R86W | Missense Mutation (SNP) | VAF 36/140 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs769344632, COSV100101187; called by muse, mutect2, varscan2
- HCN1 | c.2537C>T p.S846L | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as rs1477444033, COSV100301983, COSV57520811; called by muse, mutect2, varscan2
- HECTD4 | c.8827C>T p.L2943F | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.999); catalogued as COSV101108386; called by muse, mutect2, varscan2
- HECTD4 | c.8153T>C p.V2718A | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101108387; called by muse, mutect2, varscan2
- HERC2 | c.1997G>T p.S666I | Missense Mutation (SNP) | VAF 59/169 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.354); catalogued as COSV99871018; called by muse, mutect2, varscan2
- HERC2 | c.845C>T p.P282L | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99876801; called by muse, mutect2, varscan2
- HIF1A | c.407C>G p.T136S | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.377); catalogued as COSV100049284; called by muse, mutect2, varscan2
- HIVEP3 | c.4597G>A p.E1533K | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.023); catalogued as COSV99914043; called by muse, varscan2
- HLCS | c.493C>T p.L165F | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100358621; called by muse, mutect2, varscan2
- HMCN1 | c.6911T>G p.V2304G | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); catalogued as COSV99636026; called by muse, mutect2, varscan2
- HMGCLL1 | c.578G>A p.G193E | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51441241; called by muse, mutect2, varscan2
- HNF1B | c.452C>T p.S151F | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM104565; called by muse, mutect2, varscan2
- HTATSF1 | c.927G>A p.R309= | Splice Region (SNP) | VAF 56/170 reads (33%) | catalogued as COSV54480826; called by muse, mutect2, varscan2
- HTR5A | c.649C>T p.L217F | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV99840000; called by muse, mutect2, varscan2
- HVCN1 | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.054); catalogued as COSV99657479; called by muse, mutect2, varscan2
- HYAL2 | c.355C>T p.H119Y | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.014); catalogued as COSV99222887, COSV99222934; called by muse, mutect2, varscan2
- HYDIN | c.11026C>T p.H3676Y | Missense Mutation (SNP) | VAF 27/50 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.743); catalogued as COSV101158470; called by muse, mutect2, varscan2
- IFT140 | c.3371C>T p.A1124V | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs867516618, COSV100794521; called by muse, mutect2
- IGDCC3 | c.632C>T p.A211V | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV100031268; called by muse, mutect2, varscan2
- IGLL5 | c.452A>G p.K151R | Missense Mutation (SNP) | VAF 24/34 reads (71%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.329); catalogued as COSV101138978; called by muse, mutect2, varscan2
- IGSF10 | c.2315G>A p.R772Q | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs746715734, COSV56787782; called by muse, mutect2, varscan2
- IGSF21 | c.1090C>T p.H364Y | Missense Mutation (SNP) | VAF 32/112 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.298); catalogued as rs1324415465, COSV99243346; called by muse, mutect2, varscan2
- IKBKE | c.1529C>T p.S510F | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as COSV100898392; called by muse, mutect2, varscan2
- IL10RA | c.596G>A p.G199E | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV99923278; called by muse, mutect2, varscan2
- IL18R1 | c.578G>A p.G193E | Missense Mutation (SNP) | VAF 41/72 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99295501; called by muse, mutect2, varscan2
- IMPG1 | c.370C>T p.Q124* | Nonsense Mutation (SNP) | VAF 31/50 reads (62%) | catalogued as COSV100886195; called by muse, mutect2, varscan2
- INHBB | c.860A>G p.H287R | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.05); catalogued as COSV99736202; called by muse, mutect2, varscan2
- INSYN2A | c.84G>A p.M28I | Missense Mutation (SNP) | VAF 47/120 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.31); catalogued as rs772129249, COSV54738698, COSV54756207; called by muse, mutect2, varscan2
- INTS6L | c.208C>T p.H70Y | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV100878324; called by muse, mutect2, varscan2
- IQGAP2 | c.2054C>T p.S685L | Missense Mutation (SNP) | VAF 34/59 reads (58%) | SIFT tolerated (0.28); PolyPhen benign (0.028); catalogued as COSV57183113; called by muse, mutect2, varscan2
- IRAK4 | c.83C>T p.P28L | Missense Mutation (SNP) | VAF 31/64 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV101471848; called by muse, mutect2
- IRAK4 | c.85C>T p.Q29* | Nonsense Mutation (SNP) | VAF 31/64 reads (48%) | catalogued as COSV101471849; called by muse, mutect2
- ITGA6 | c.1157T>C p.V386A (on ENST00000442250; = p.V347A on NM_000210.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/65 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); catalogued as rs987707617, COSV99906119; called by muse, mutect2, varscan2
- ITGA8 | c.1073G>A p.G358E | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100959767; called by muse, mutect2, varscan2
- ITGBL1 | c.505G>A p.G169R | Missense Mutation (SNP) | VAF 62/133 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.065); catalogued as COSV101095774; called by muse, mutect2, varscan2
- ITM2A | c.304C>T p.R102C | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.182); catalogued as rs1329119797, COSV100964494; called by muse, mutect2, varscan2
- ITPR1 | c.2263G>A p.E755K (on ENST00000354582; = p.E740K on NM_002222.7) | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.33); PolyPhen benign (0.062); catalogued as COSV56996351; called by muse, mutect2, varscan2
- ITPR1 | c.4480C>T p.P1494S (on ENST00000354582; = p.P1479S on NM_002222.7) | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56976241; called by muse, mutect2, varscan2
- IZUMO1R | c.382G>A p.D128N (on ENST00000440961; = p.D135N on NM_001199206.3) | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.86); catalogued as COSV100126935; called by muse, mutect2, varscan2
- KANSL1 | c.409A>T p.N137Y | Missense Mutation (SNP) | VAF 70/254 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99294962; called by muse, mutect2
- KCNC1 | c.1222C>T p.P408S | Missense Mutation (SNP) | VAF 37/108 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99789753; called by muse, mutect2, varscan2
- KCND3 | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated (0.2); PolyPhen benign (0.01); catalogued as COSV100138472; called by muse, mutect2, varscan2
- KCNH2 | c.2503C>T p.R835W | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.679); catalogued as rs199473003, CD154178, CM040439, COSV100061119; ClinVar: not provided; called by muse, mutect2, varscan2
- KCNH3 | c.2966G>A p.R989Q | Missense Mutation (SNP) | VAF 35/70 reads (50%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as rs143655453; called by muse, mutect2, varscan2
- KCNU1 | c.2602C>T p.P868S | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.536); catalogued as COSV67760513; called by muse, mutect2, varscan2
- KDM4A | c.2785G>T p.E929* | Nonsense Mutation (SNP) | VAF 20/81 reads (25%) | catalogued as COSV100969666; called by muse, mutect2, varscan2
- KEL | c.530G>A p.G177E | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62333418; called by muse, mutect2
- KIAA0513 | c.260C>T p.T87I | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0.036); catalogued as COSV99261326; called by muse, mutect2, varscan2
- KIAA1210 | c.3820G>A p.V1274I | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.785); catalogued as COSV101274402; called by muse, mutect2, varscan2
- KIAA1210 | c.1205C>T p.S402L | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68176542; called by muse, mutect2, varscan2
- KIF15 | c.3445C>T p.Q1149* | Nonsense Mutation (SNP) | VAF 15/56 reads (27%) | catalogued as COSV100393273, COSV58162096; called by muse, mutect2, varscan2
- KIF4B | c.1105C>T p.H369Y | Missense Mutation (SNP) | VAF 10/107 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.105); catalogued as rs760862480, COSV70530922; called by muse, mutect2
- KIR3DL1 | c.542C>T p.S181F | Missense Mutation (SNP) | VAF 96/239 reads (40%) | SIFT tolerated (0.24); PolyPhen benign (0.146); catalogued as COSV58487991; called by muse, mutect2, varscan2
- KIR3DL3 | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 62/161 reads (39%) | SIFT tolerated (0.97); PolyPhen benign (0.003); catalogued as rs1385416819; called by muse, mutect2, varscan2
- KL | c.1703G>A p.R568K | Missense Mutation (SNP) | VAF 43/123 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as rs991174207, COSV101199011; called by muse, mutect2, varscan2
- KLKB1 | c.1517C>T p.S506F | Missense Mutation (SNP) | VAF 24/34 reads (71%) | SIFT deleterious (0.02); PolyPhen benign (0.074); catalogued as COSV99250448; called by muse, mutect2, varscan2
- KNDC1 | c.5167G>A p.A1723T | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.062); catalogued as COSV100466285; called by muse, mutect2, varscan2
- KNL1 | c.2047C>T p.P683S (on ENST00000346991 / NM_170589.5; = p.P657S on NM_144508.5) | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs920756297, COSV100707069; called by muse, mutect2, varscan2
- KPNA3 | c.775C>T p.L259F | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99904388; called by muse, mutect2, varscan2
- KRBA1 | c.2311C>T p.P771S | Missense Mutation (SNP) | VAF 26/129 reads (20%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.492); catalogued as COSV99753137; called by muse, mutect2, varscan2
- KRT24 | c.109G>A p.G37S | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.021); catalogued as COSV99232171; called by muse, mutect2, varscan2
- KRT26 | c.713G>A p.G238E | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV59415682; called by muse, mutect2, varscan2
- KRT26 | c.712G>A p.G238R | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV59412510; called by muse, mutect2, varscan2
- KRT28 | c.922G>A p.E308K | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.869); catalogued as COSV60683787; called by muse, mutect2, varscan2
- KRT5 | c.23C>T p.S8F | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs913174272, COSV99357876; called by muse, mutect2, varscan2
- KRTAP13-1 | c.149C>T p.S50F | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV100819933; called by muse, mutect2, varscan2
- KRTAP9-9 | c.398C>T p.S133F | Missense Mutation (SNP) | VAF 77/201 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV101223552; called by muse, mutect2, varscan2
- KTN1 | c.746G>C p.R249T | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101255456; called by muse, mutect2, varscan2
- L1CAM | c.1312G>A p.A438T | Missense Mutation (SNP) | VAF 36/109 reads (33%) | SIFT tolerated (0.38); PolyPhen benign (0.074); catalogued as COSV100649477; called by muse, mutect2, varscan2
- L1CAM | c.1311G>A p.M437I | Missense Mutation (SNP) | VAF 36/109 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as COSV100649478; called by muse, mutect2, varscan2
- L1TD1 | c.451G>A p.E151K | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs771642989, COSV63133649, COSV63134389; called by muse, mutect2, varscan2
- L3MBTL1 | c.1016C>T p.P339L (on ENST00000418998 / NM_001377303.1; = p.P249L on NM_015478.7) | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100917063; called by muse, mutect2
- LAMA2 | c.6403A>C p.N2135H | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV101370842; called by muse, mutect2, varscan2
- LAMB1 | c.623G>A p.R208H | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1424457865, COSV99741708; called by muse, mutect2, varscan2
- LAMC2 | c.1259G>A p.G420E | Missense Mutation (SNP) | VAF 69/160 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as rs763994158, COSV99917982; called by muse, mutect2, varscan2
- LARP4 | c.1285G>T p.E429* | Nonsense Mutation (SNP) | VAF 25/75 reads (33%) | catalogued as COSV99529702; called by muse, mutect2, varscan2
- LAS1L | c.1747G>A p.E583K | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV100408694; called by muse, mutect2, varscan2
- LCE1D | c.209G>T p.G70V | Missense Mutation (SNP) | VAF 26/35 reads (74%) | PolyPhen probably damaging (0.999); catalogued as COSV58271658; called by muse, mutect2, varscan2
- LCT | c.1264G>A p.G422S | Missense Mutation (SNP) | VAF 37/75 reads (49%) | SIFT tolerated (0.34); PolyPhen benign (0.018); catalogued as COSV99930493; called by muse, mutect2, varscan2
- LIAS | c.462G>T p.Q154H (on ENST00000261434 / NM_001363700.2; = p.Q257H on NM_006859.4) | Missense Mutation (SNP) | VAF 33/47 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99787889; called by muse, mutect2, varscan2
- LIFR | c.1171G>A p.E391K | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT tolerated (0.36); PolyPhen benign (0.006); catalogued as rs373421600; called by muse, mutect2, varscan2
- LILRA4 | c.707C>T p.P236L | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.311); catalogued as rs1475217767, COSV99393077, COSV99393394; called by muse, mutect2, varscan2
- LILRB1 | c.2021G>A p.R674K (on ENST00000427581; = p.R623K on NM_006669.6) | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.169); catalogued as COSV100207927; called by muse, mutect2, varscan2
- LILRB3 | c.356G>A p.G119E | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs1370604736, COSV99558506; called by muse, mutect2, varscan2
- LILRB4 | c.413A>G p.K138R | Missense Mutation (SNP) | VAF 38/116 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as COSV99554125; called by muse, mutect2
- LIMK1 | c.1667C>T p.T556I | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as rs1554700444, COSV100283477; called by muse, mutect2, varscan2
- LINGO4 | c.1738G>A p.D580N | Missense Mutation (SNP) | VAF 39/108 reads (36%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as rs200969208, COSV100917574; called by muse, mutect2, varscan2
- LINS1 | c.1952C>T p.S651F | Missense Mutation (SNP) | VAF 38/100 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.988); catalogued as COSV59078069; called by muse, mutect2, varscan2
- LMX1A | c.1097G>A p.G366E | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs145918505; called by muse, mutect2, varscan2
- LRFN2 | c.1594G>A p.G532S | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1485565179, COSV57824137, COSV57831955; called by muse, mutect2, varscan2
- LRFN2 | c.470C>T p.S157F | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57824381; called by muse, mutect2, varscan2
- LRRIQ3 | c.1855C>T p.P619S | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.014); catalogued as COSV63046147; called by muse, mutect2, varscan2
- LRRIQ3 | c.1135C>T p.P379S | Missense Mutation (SNP) | VAF 34/105 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0.087); catalogued as rs866672669, COSV63041491; called by muse, mutect2, varscan2
- LTBP1 | c.3730G>A p.D1244N (on ENST00000404816 / NM_206943.4; = p.D918N on NM_000627.4) | Missense Mutation (SNP) | VAF 32/65 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55383190; called by muse, mutect2, varscan2
- LTK | c.2401G>A p.E801K | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.915); catalogued as COSV99541187; called by muse, mutect2, varscan2
- LTO1 | c.70C>T p.R24W | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs149170616; called by muse, mutect2, varscan2
- MACF1 | c.15770C>T p.A5257V (on ENST00000372915; = p.A3190V on NM_012090.5) | Missense Mutation (SNP) | VAF 16/75 reads (21%) | catalogued as rs1291598485, COSV99246954; called by muse, mutect2, varscan2
- MAGEC1 | c.1786C>T p.P596S | Missense Mutation (SNP) | VAF 144/438 reads (33%) | SIFT tolerated, low confidence (0.15); PolyPhen probably damaging (0.968); catalogued as COSV53569060; called by muse, mutect2, varscan2
- MAGEC1 | c.2731A>T p.K911* | Nonsense Mutation (SNP) | VAF 101/272 reads (37%) | catalogued as COSV99596610; called by muse, mutect2, varscan2
- MAGEC2 | c.323C>T p.S108L | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT tolerated (0.23); PolyPhen benign (0.424); catalogued as COSV55998321, COSV56002040; called by muse, mutect2, varscan2
- MAGI1 | c.1439G>C p.R480P | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV100441870, COSV100443176; called by muse, mutect2, varscan2
- MAOB | c.287C>T p.S96L | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.031); catalogued as COSV100956248; called by muse, mutect2, varscan2
- MAP2 | c.856C>T p.P286S | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.091); catalogued as COSV99561785; called by muse, mutect2, varscan2
- MAP3K14 | c.775C>T p.P259S | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.601); catalogued as COSV60925390; called by muse, mutect2, varscan2
- MAP3K15 | c.1063C>T p.H355Y | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.834); catalogued as COSV58838458; called by muse, mutect2, varscan2
- MAP3K5 | c.2897C>T p.S966F | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as COSV100752591; called by muse, mutect2, varscan2
- MAP3K7 | c.137C>T p.A46V | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.063); catalogued as COSV100997947; called by muse, mutect2, varscan2
- MARCO | c.986C>T p.S329F | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.316); catalogued as rs142580121; called by muse, mutect2, varscan2
- MCM4 | c.629T>C p.V210A | Missense Mutation (SNP) | VAF 54/167 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.271); catalogued as COSV100031849; called by muse, mutect2, varscan2
- MCMDC2 | c.943C>T p.P315S | Missense Mutation (SNP) | VAF 41/99 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.476); catalogued as rs201328764, COSV100552333; called by muse, mutect2, varscan2
- MCTP2 | c.2581G>A p.E861K | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.86); catalogued as COSV100752520, COSV63296966; called by muse, mutect2, varscan2
- MDC1 | c.3230C>T p.T1077I | Missense Mutation (SNP) | VAF 40/206 reads (19%) | SIFT tolerated (0.5); PolyPhen benign (0.139); catalogued as COSV100903095; called by muse, mutect2, varscan2
- MED16 | c.1966C>T p.R656W | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs750429963, COSV54125651, COSV99514933; called by muse, mutect2
- MED26 | c.1684G>A p.G562R | Missense Mutation (SNP) | VAF 38/53 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54660553; called by muse, mutect2, varscan2
- METTL1 | c.409C>T p.L137F | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); catalogued as rs538212914, COSV99141660; called by muse, mutect2, varscan2
- MFAP1 | c.5C>A p.S2* | Nonsense Mutation (SNP) | VAF 30/59 reads (51%) | catalogued as COSV99776781; called by muse, mutect2
- MFAP1 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 30/59 reads (51%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.38); catalogued as COSV99776782; called by muse, mutect2
- MGAT4C | c.599C>T p.S200F | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100153419; called by muse, mutect2, varscan2
- MMP13 | c.568C>T p.P190S | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.163); catalogued as rs1413504149, COSV52825684; called by muse, mutect2, varscan2
- MORC3 | c.1346C>T p.P449L | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.517); catalogued as COSV101247766, COSV68203725; called by muse, mutect2, varscan2
- MORC4 | c.1823G>A p.G608E | Missense Mutation (SNP) | VAF 66/207 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.356); catalogued as COSV99717636; called by muse, mutect2, varscan2
- MPEG1 | c.1375G>A p.E459K | Missense Mutation (SNP) | VAF 64/131 reads (49%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV99915952; called by muse, mutect2, varscan2
- MPP1 | c.424G>A p.G142R | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101053760; called by muse, mutect2, varscan2
- MRPL51 | c.136C>T p.R46C | Missense Mutation (SNP) | VAF 51/114 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99975265; called by muse, mutect2, varscan2
- MSN | c.256C>T p.P86S | Missense Mutation (SNP) | VAF 36/110 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100814313; called by muse, mutect2, varscan2
- MSRB3 | c.311C>T p.S104L | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); catalogued as COSV100378323; called by muse, mutect2, varscan2
- MTUS2 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV70915988; called by muse, mutect2, varscan2
- MTX2 | c.50C>T p.P17L | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV99981427; called by muse, mutect2, varscan2
- MUC16 | c.38066C>T p.P12689L | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs764363718, COSV101201473, COSV101201774; called by muse, mutect2, varscan2
- MUC16 | c.29087G>A p.G9696E | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.007); catalogued as COSV67482472; called by muse, mutect2, varscan2
- MUC16 | c.23999C>T p.P8000L | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.068); catalogued as COSV101201776; called by muse, mutect2, varscan2
- MUC16 | c.11607G>A p.W3869* | Nonsense Mutation (SNP) | VAF 21/43 reads (49%) | catalogued as rs1396011870, COSV101201777; called by muse, mutect2, varscan2
- MUC16 | c.9325G>A p.E3109K | Missense Mutation (SNP) | VAF 75/181 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.801); catalogued as COSV67491873; called by muse, mutect2, varscan2
- MUC16 | c.8204C>T p.P2735L | Missense Mutation (SNP) | VAF 59/130 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.958); catalogued as COSV67468136; called by muse, mutect2, varscan2
- MUC16 | c.5402G>A p.G1801E | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.087); catalogued as rs1278773448, COSV67504277; called by muse, mutect2, varscan2
- MUC16 | c.2675C>T p.S892F | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.934); catalogued as COSV101201778, COSV67466526; called by muse, mutect2, varscan2
- MUC17 | c.3473G>A p.G1158E | Missense Mutation (SNP) | VAF 75/372 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV60305435; called by muse, mutect2, varscan2
- MUC17 | c.4181G>A p.G1394E | Missense Mutation (SNP) | VAF 77/336 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.29); catalogued as COSV60307565; called by muse, mutect2, varscan2
- MUC17 | c.8026A>G p.T2676A | Missense Mutation (SNP) | VAF 77/196 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.286); catalogued as COSV100075105; called by muse, mutect2, varscan2
- MUC2 | c.2569C>T p.P857S | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.03); catalogued as rs772381817; called by muse, mutect2, varscan2
- MUSK | c.263G>A p.S88N | Missense Mutation (SNP) | VAF 44/72 reads (61%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0.026); catalogued as rs772270944, COSV99505172; called by muse, mutect2, varscan2
- MXRA5 | c.4802C>T p.A1601V | Missense Mutation (SNP) | VAF 57/124 reads (46%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV54250453, COSV99479366; called by muse, mutect2, varscan2
- MXRA5 | c.4556C>T p.S1519F | Missense Mutation (SNP) | VAF 66/145 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.231); catalogued as COSV99479369; called by muse, mutect2, varscan2
- MXRA5 | c.3724C>T p.R1242* | Nonsense Mutation (SNP) | VAF 74/169 reads (44%) | catalogued as COSV99479372; called by muse, mutect2, varscan2
- MXRA5 | c.2979G>A p.M993I | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV99479374; called by muse, mutect2, varscan2
- MYH2 | c.5392G>A p.D1798N | Missense Mutation (SNP) | VAF 42/106 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV55437087, COSV55448689; called by muse, mutect2, varscan2
- MYH8 | c.3255G>A p.K1085= | Splice Region (SNP) | VAF 27/60 reads (45%) | catalogued as COSV67959126; called by muse, mutect2
- MYH8 | c.2632G>A p.E878K | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.141); catalogued as COSV67959790; called by muse, mutect2, varscan2
- MYLK4 | c.848C>T p.P283L | Missense Mutation (SNP) | VAF 65/162 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.609); catalogued as COSV99193906; called by muse, mutect2, varscan2
- MYO15A | c.8276G>A p.R2759Q | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as rs374534318; called by muse, mutect2, varscan2
- MYOCD | c.1270C>T p.P424S | Missense Mutation (SNP) | VAF 38/101 reads (38%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV58506770; called by muse, mutect2, varscan2
- MYOCD | c.2569T>G p.L857V | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.145); catalogued as COSV100591462; called by muse, mutect2, varscan2
- NAV3 | c.6103C>T p.P2035S (on ENST00000397909 / NM_001024383.2; = p.P2013S on NM_014903.6) | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57117615; called by muse, mutect2, varscan2
- NBPF1 | c.2569C>T p.H857Y | Missense Mutation (SNP) | VAF 80/382 reads (21%) | SIFT tolerated (1); PolyPhen probably damaging (0.947); catalogued as COSV55321186; called by muse, mutect2, varscan2
- NDUFC2 | c.346C>T p.H116Y | Missense Mutation (SNP) | VAF 27/47 reads (57%) | SIFT tolerated (0.97); PolyPhen benign (0.011); catalogued as COSV99806570; called by muse, mutect2, varscan2
- NEK4 | c.947C>T p.S316F | Missense Mutation (SNP) | VAF 42/82 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.312); catalogued as COSV51778905; called by muse, mutect2, varscan2
- NELFCD | c.390T>A p.S130R (on ENST00000602795; = p.S112R on NM_198976.4) | Missense Mutation (SNP) | VAF 38/117 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.243); catalogued as COSV100682983; called by muse, mutect2, varscan2
- NELL1 | c.1230G>A p.W410* | Nonsense Mutation (SNP) | VAF 33/86 reads (38%) | catalogued as COSV100118600, COSV100125364; called by muse, mutect2, varscan2
- NENF | c.319C>T p.P107S | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.182); catalogued as COSV100877102; called by muse, mutect2, varscan2
- NEUROD4 | c.820G>A p.E274K | Missense Mutation (SNP) | VAF 88/236 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.021); catalogued as COSV54474704, COSV99670175; called by muse, mutect2, varscan2
- NEXMIF | c.579G>A p.M193I | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT tolerated (0.95); PolyPhen benign (0.001); catalogued as COSV50032912, COSV99281438; called by muse, mutect2, varscan2
- NID2 | c.362G>A p.R121Q | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as rs1271276662, COSV99357309; called by muse, mutect2, varscan2
- NIM1K | c.118G>A p.G40R | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT tolerated (0.44); PolyPhen benign (0.009); catalogued as COSV100390484; called by muse, mutect2, varscan2
- NIM1K | c.640G>A p.D214N | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770782986, COSV100390488; called by muse, mutect2, varscan2
- NLRP14 | c.14C>T p.S5L | Missense Mutation (SNP) | VAF 52/135 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs1204806522, COSV55063581; called by muse, mutect2, varscan2
- NLRP2 | c.2575G>A p.D859N | Missense Mutation (SNP) | VAF 48/102 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.097); catalogued as COSV99672675; called by muse, mutect2, varscan2
- NLRP5 | c.2623T>C p.C875R | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV101173882; called by muse, mutect2, varscan2
- NLRP8 | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 46/93 reads (49%) | SIFT tolerated (0.21); PolyPhen benign (0.029); catalogued as COSV52593825; called by muse, mutect2, varscan2
- NME8 | c.1045A>T p.R349* | Nonsense Mutation (SNP) | VAF 30/78 reads (38%) | catalogued as COSV99553872; called by muse, mutect2
- NOS1 | c.3956G>A p.R1319Q | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.792); catalogued as rs1330112610, COSV57610393; called by muse, mutect2, varscan2
- NOS1 | c.1253C>T p.S418L | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.41); catalogued as rs766387733, COSV100501325; called by muse, mutect2, varscan2
- NOS1 | c.76G>A p.G26R | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100501448; called by muse, mutect2, varscan2
- NOS1AP | c.731G>A p.G244E | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0.024); catalogued as COSV100723637; called by muse, mutect2, varscan2
- NOVA1 | c.1365A>G p.I455M | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99948791; called by muse, mutect2, varscan2
- NPTN | c.794C>G p.P265R | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99766895; called by muse, mutect2, varscan2
- NRG1 | c.835C>T p.R279W (on ENST00000405005 / NM_013964.5; = p.R284W on NM_013956.5) | Missense Mutation (SNP) | VAF 60/130 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs367543163, COSV55174145; called by muse, mutect2, varscan2
- NRK | c.4295G>A p.G1432E | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs267606301, COSV99688965; called by muse, mutect2, varscan2
- NRP1 | c.2534G>A p.R845K | Missense Mutation (SNP) | VAF 41/84 reads (49%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as COSV99589638; called by muse, mutect2, varscan2
- NRXN1 | c.3363C>T p.D1121= | Splice Region (SNP) | VAF 9/24 reads (38%) | catalogued as COSV100456944; called by muse, mutect2
- NT5C1B | c.346C>T p.L116F (on ENST00000359846 / NM_001199086.2; = p.L56F on NM_033253.4) | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.206); catalogued as COSV100410302; called by muse, mutect2
- NTRK3 | c.1250C>T p.P417L | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.009); catalogued as rs1442871238, COSV100448123, COSV58120910; called by muse, mutect2, varscan2
- NUP214 | c.3068C>T p.S1023F | Missense Mutation (SNP) | VAF 60/80 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100845397; called by muse, mutect2, varscan2
- NUP58 | c.782T>C p.F261S | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV101098919; called by muse, mutect2, varscan2
- NYAP2 | c.1327G>A p.G443R | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as COSV99796518; called by muse, mutect2
- OPN4 | c.1000G>A p.V334M | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54118793; called by muse, mutect2, varscan2
- OPN5 | c.703C>T p.H235Y | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.366); catalogued as COSV99790056; called by muse, mutect2, varscan2
- OPRM1 | c.653A>G p.D218G | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.056); catalogued as COSV100002490; called by muse, mutect2, varscan2
- OR10J1 | c.485C>T p.S162F | Missense Mutation (SNP) | VAF 70/158 reads (44%) | SIFT tolerated (0.71); PolyPhen probably damaging (0.972); catalogued as COSV71128742, COSV71129218; called by muse, mutect2, varscan2
- OR10J3 | c.727G>A p.A243T | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.365); catalogued as rs762786872, COSV59955799; called by muse, mutect2, varscan2
- OR10J5 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.378); catalogued as rs760004484, COSV100604845; called by muse, mutect2, varscan2
- OR11G2 | c.605C>T p.S202F | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.6); catalogued as COSV62133072; called by muse, mutect2, varscan2
- OR11L1 | c.805G>A p.E269K | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT tolerated (0.37); PolyPhen benign (0.196); catalogued as rs866164111, COSV63313503; called by muse, mutect2, varscan2
- OR1A1 | c.778C>T p.R260C | Missense Mutation (SNP) | VAF 50/139 reads (36%) | SIFT tolerated (0.44); PolyPhen benign (0.06); catalogued as rs765272168, COSV58404653; called by muse, mutect2, varscan2
- OR2A25 | c.883G>A p.E295K | Missense Mutation (SNP) | VAF 137/232 reads (59%) | SIFT deleterious (0); PolyPhen benign (0.257); catalogued as COSV68717133; called by muse, mutect2, varscan2
- OR2G6 | c.544C>T p.P182S | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1178603372, COSV100598326; called by muse, mutect2, varscan2
- OR2M3 | c.494C>T p.S165F | Missense Mutation (SNP) | VAF 89/237 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.182); catalogued as rs267598500, COSV71759081; called by muse, mutect2, varscan2
- OR2M3 | c.700C>T p.R234C | Missense Mutation (SNP) | VAF 160/390 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as rs748575324, COSV101513390, COSV71758967; called by muse, mutect2, varscan2
- OR2T33 | c.629C>T p.S210F | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.327); catalogued as rs756717060, COSV58814950; called by muse, mutect2
- OR2T8 | c.629C>T p.S210F | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.327); catalogued as rs764332590, COSV100177967; called by muse, mutect2
- OR4A47 | c.55C>T p.P19S | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.035); catalogued as rs267602921, COSV101487129, COSV71444871; called by muse, varscan2
- OR4D5 | c.16C>T p.H6Y | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100189791, COSV100190016; called by muse, mutect2, varscan2
- OR4X1 | c.348G>A p.M116I | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1164019743, COSV100186838; called by muse, mutect2, varscan2
- OR51A7 | c.316G>A p.G106R | Missense Mutation (SNP) | VAF 47/119 reads (39%) | SIFT tolerated (0.27); PolyPhen benign (0.151); catalogued as COSV100834765; called by muse, mutect2, varscan2
- OR51B2 | c.488C>T p.S163L | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT tolerated (0.65); PolyPhen benign (0.216); catalogued as COSV60915972; called by muse, varscan2
- OR51B5 | c.926G>A p.R309K | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.37); PolyPhen benign (0.006); catalogued as COSV56174995, COSV56177634; called by muse, mutect2, varscan2
- OR52H1 | c.656C>T p.S219F (on ENST00000322653; = p.S225F on NM_001005289.1) | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867402371, COSV59504952; called by muse, mutect2, varscan2
- OR52L1 | c.470G>A p.G157E | Missense Mutation (SNP) | VAF 29/52 reads (56%) | SIFT tolerated (0.2); PolyPhen benign (0.041); catalogued as COSV59989566; called by muse, mutect2, varscan2
- OR5H15 | c.273G>A p.M91I | Missense Mutation (SNP) | VAF 83/178 reads (47%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV62949074; called by muse, mutect2, varscan2
- OR5H6 | c.463G>A p.E155K (on ENST00000642105; = p.E139K on NM_001005479.2) | Missense Mutation (SNP) | VAF 29/154 reads (19%) | SIFT tolerated (0.52); PolyPhen benign (0.006); catalogued as COSV67351004, COSV67351507; called by muse, mutect2, varscan2
- OR5I1 | c.869T>G p.L290W | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV100041714; called by muse, mutect2, varscan2
- OR5M3 | c.692G>A p.G231E | Missense Mutation (SNP) | VAF 35/101 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100392690; called by muse, mutect2, varscan2
- OR8B2 | c.428T>G p.M143R | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.14); catalogued as COSV100899504; called by muse, mutect2, varscan2
- OR8B2 | c.187C>T p.L63F | Missense Mutation (SNP) | VAF 45/114 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV100899505; called by muse, mutect2
- OR8H2 | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 72/213 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.864); catalogued as rs1186349616, COSV57943626; called by muse, mutect2, varscan2
- OR8H3 | c.664C>T p.L222F | Missense Mutation (SNP) | VAF 73/190 reads (38%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.521); catalogued as rs1339637935, COSV100539153, COSV57907640; called by muse, varscan2
- OR8H3 | c.698G>A p.G233E | Missense Mutation (SNP) | VAF 64/145 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); catalogued as rs547287374, COSV57909356; called by muse, varscan2
- OR9K2 | c.80G>A p.G27E (on ENST00000305377; = p.G5E on NM_001005243.1) | Missense Mutation (SNP) | VAF 53/111 reads (48%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as rs139798501; called by muse, mutect2, varscan2
- ORAI1 | c.536C>T p.S179F | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100345504; called by muse, mutect2, varscan2
- OSBPL1A | c.1878C>G p.N626K (on ENST00000319481 / NM_080597.4; = p.N113K on NM_018030.4) | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100112800; called by muse, mutect2, varscan2
- OSBPL3 | c.758C>T p.P253L | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100514584; called by muse, mutect2, varscan2
- OTOP2 | c.1282G>A p.G428R | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.49); PolyPhen benign (0.072); catalogued as COSV100173073; called by muse, mutect2, varscan2
- OTX2 | c.608C>T p.S203L (on ENST00000408990 / NM_172337.3; = p.S211L on NM_021728.4) | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); catalogued as COSV59767727; called by muse, mutect2, varscan2
- P3H2 | c.1228C>T p.R410W | Missense Mutation (SNP) | VAF 45/105 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs1307588537, COSV60027650; called by muse, mutect2, varscan2
- PAFAH2 | c.692C>T p.A231V | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV100959382; called by muse, mutect2, varscan2
- PAH | c.631C>T p.P211S | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.965); catalogued as CM930544, COSV61015784; called by muse, mutect2, varscan2
- PAPPA2 | c.1822G>A p.D608N | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62780891; called by muse, mutect2, varscan2
- PAX7 | c.1300G>A p.D434N | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.993); catalogued as rs1489518352, COSV100946979; called by muse, mutect2, varscan2
- PCARE | c.1679G>A p.G560E | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT tolerated (0.24); PolyPhen benign (0.062); catalogued as COSV100527893; called by muse, mutect2, varscan2
- PCDH9 | c.3230G>A p.G1077E (on ENST00000377865 / NM_203487.3; = p.G1043E on NM_020403.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.446); catalogued as COSV60531760; called by muse, mutect2, varscan2
- PCDHA3 | c.263C>T p.S88F | Missense Mutation (SNP) | VAF 84/127 reads (66%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.612); catalogued as rs1231634560, COSV100974156; called by muse, mutect2, varscan2
- PCDHA3 | c.562G>A p.E188K | Missense Mutation (SNP) | VAF 30/41 reads (73%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.007); catalogued as rs782260016, COSV65365377, COSV65367658; called by muse, mutect2, varscan2
- PCDHA3 | c.1126G>A p.D376N | Missense Mutation (SNP) | VAF 40/59 reads (68%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as rs1459793883, COSV100793757; called by muse, mutect2, varscan2
- PCDHA9 | c.580C>T p.L194F | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.957); catalogued as rs781949209, COSV100970123; called by muse, varscan2
- PCDHB14 | c.1169C>A p.P390H | Missense Mutation (SNP) | VAF 44/69 reads (64%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV99506300; called by muse, mutect2, varscan2
- PCDHB4 | c.2251G>A p.E751K | Missense Mutation (SNP) | VAF 13/151 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.081); catalogued as rs782620651, COSV52021200; called by muse, mutect2
- PCLO | c.12173G>A p.G4058E | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT tolerated (0.2); PolyPhen benign (0.04); catalogued as COSV100438021; called by muse, mutect2, varscan2
- PCLO | c.6482C>T p.S2161L | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.683); catalogued as rs950381444, COSV61618405; called by muse, mutect2, varscan2
- PCLO | c.6207G>A p.M2069I | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV100438033; called by muse, mutect2, varscan2
- PCLO | c.994C>T p.P332S | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); catalogued as rs750767479, COSV100438040; called by muse, mutect2, varscan2
- PCLO | c.575A>T p.K192I | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.943); catalogued as COSV100438042; called by muse, mutect2, varscan2
- PDC | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 38/82 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.954); catalogued as COSV100414884; called by muse, mutect2, varscan2
- PDE1A | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 46/102 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs145482728, COSV59527650; called by muse, mutect2, varscan2
- PDE3A | c.1118C>T p.S373F | Missense Mutation (SNP) | VAF 36/83 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV62976403; called by muse, mutect2, varscan2
- PDE3A | c.2603A>C p.H868P | Missense Mutation (SNP) | VAF 50/146 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100762823; called by muse, mutect2, varscan2
- PDE4DIP | c.6464C>T p.P2155L | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as COSV100516296; called by mutect2, varscan2
- PENK | c.383G>A p.G128E | Missense Mutation (SNP) | VAF 67/125 reads (54%) | SIFT tolerated (0.12); PolyPhen benign (0.439); catalogued as COSV100152484; called by muse, mutect2, varscan2
- PHKA1 | c.2806C>T p.R936* | Nonsense Mutation (SNP) | VAF 31/66 reads (47%) | catalogued as COSV59808697; called by muse, mutect2, varscan2
- PHLDB2 | c.2221G>A p.E741K (on ENST00000393925 / NM_001134439.2; = p.E698K on NM_145753.2) | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101208716; called by muse, mutect2, varscan2
- PIAS2 | c.839C>A p.S280Y | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as rs763194678, COSV100245537; called by muse, mutect2, varscan2
- PIGU | c.1276G>A p.D426N | Missense Mutation (SNP) | VAF 25/45 reads (56%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.746); catalogued as COSV99466893; called by muse, mutect2, varscan2
- PITHD1 | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV99862243; called by muse, mutect2, varscan2
- PITPNM2 | c.929C>T p.S310L | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as rs1192011310, COSV54897562; called by muse, mutect2, varscan2
- PIWIL2 | c.166G>A p.E56K | Missense Mutation (SNP) | VAF 29/111 reads (26%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.015); catalogued as COSV63252500; called by muse, mutect2, varscan2
- PIWIL2 | c.1675G>A p.D559N | Missense Mutation (SNP) | VAF 34/69 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV100769548; called by muse, mutect2, varscan2
- PKD1 | c.1317G>A p.W439* | Nonsense Mutation (SNP) | VAF 7/16 reads (44%) | catalogued as COSV99239080; called by muse, mutect2, varscan2
- PKD1 | c.1316G>A p.W439* | Nonsense Mutation (SNP) | VAF 7/16 reads (44%) | catalogued as COSV99239083; called by muse, mutect2, varscan2
- PKD2L1 | c.1245G>A p.M415I | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV100559460; called by muse, mutect2, varscan2
- PKDREJ | c.5146A>G p.T1716A | Missense Mutation (SNP) | VAF 40/54 reads (74%) | SIFT deleterious (0.05); PolyPhen benign (0.006); catalogued as rs778516145, COSV99479557; called by muse, mutect2, varscan2
- PKHD1L1 | c.2612C>A p.P871Q | Missense Mutation (SNP) | VAF 49/96 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs1413811031, COSV101006861; called by muse, mutect2, varscan2
- PLAAT5 | c.722G>A p.R241K | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV100080644; called by muse, mutect2, varscan2
- PLG | c.1988G>A p.R663Q | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT tolerated (0.61); PolyPhen benign (0.038); catalogued as rs576737789, COSV57514358; called by muse, mutect2, varscan2
- PLXNB2 | c.1949C>T p.S650L | Missense Mutation (SNP) | VAF 26/33 reads (79%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.636); catalogued as rs1004979336, COSV100834077, COSV63783640; called by muse, mutect2, varscan2
- PNLIP | c.634G>A p.D212N | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs771357615, COSV65039680; called by muse, mutect2, varscan2
- POF1B | c.726G>A p.V242= | Splice Region (SNP) | VAF 30/73 reads (41%) | catalogued as rs879091306, COSV99427446; called by muse, mutect2, varscan2
- POLQ | c.2694G>A p.W898* | Nonsense Mutation (SNP) | VAF 32/130 reads (25%) | catalogued as COSV99952998; called by muse, mutect2, varscan2
- POM121L12 | c.395G>A p.R132Q | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.42); PolyPhen benign (0.045); catalogued as rs763758598, COSV68692885; called by muse, mutect2
- POTEE | c.2821G>A p.E941K | Missense Mutation (SNP) | VAF 54/153 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.341); catalogued as rs543390483, COSV58225988, COSV58239043; called by muse, mutect2, varscan2
- PPP1R3F | c.2303G>A p.G768E | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.723); catalogued as COSV99279026; called by muse, mutect2, varscan2
- PPP2R1B | c.368C>T p.S123F | Missense Mutation (SNP) | VAF 17/27 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100232403; called by muse, mutect2, varscan2
- PRAMEF1 | c.58G>A p.D20N | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT tolerated (0.4); PolyPhen benign (0.12); catalogued as COSV100180193; called by muse, mutect2, varscan2
- PRDM9 | c.1544G>A p.G515E | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.017); catalogued as rs1317193880, COSV57007307, COSV99691291; called by muse, mutect2, varscan2
- PRDM9 | c.1729G>A p.E577K | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.639); catalogued as COSV99691292; called by muse, varscan2
- PREP | c.1122T>A p.I374= (on ENST00000369110; = p.I440= on NM_002726.5) | Splice Region (SNP) | VAF 12/56 reads (21%) | catalogued as COSV100964121; called by muse, mutect2, varscan2
- PRKAG2 | c.1247C>T p.P416L | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.361); catalogued as COSV99836079; called by muse, mutect2, varscan2
- PRRG3 | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100948703, COSV64850848; called by muse, varscan2
- PRTG | c.3281C>T p.S1094F | Missense Mutation (SNP) | VAF 44/112 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.365); catalogued as COSV101221454; called by muse, mutect2, varscan2
- PRUNE2 | c.4384G>A p.D1462N | Missense Mutation (SNP) | VAF 35/53 reads (66%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs760795173, COSV100945159; called by muse, mutect2, varscan2
- PSD3 | c.1507G>A p.D503N | Missense Mutation (SNP) | VAF 55/179 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.316); catalogued as COSV100497241; called by muse, mutect2, varscan2
- PTK2B | c.2817C>T p.I939= | Splice Region (SNP) | VAF 8/37 reads (22%) | catalogued as rs530386451, COSV53559107; called by muse, mutect2, varscan2
- PTPN21 | c.2815G>A p.E939K | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.994); catalogued as COSV100162550; called by muse, mutect2, varscan2
- PUM3 | c.950C>G p.A317G | Missense Mutation (SNP) | VAF 24/35 reads (69%) | SIFT tolerated (0.14); PolyPhen benign (0.049); catalogued as COSV101193238; called by muse, mutect2, varscan2
- R3HDM4 | c.79C>T p.P27S | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); catalogued as rs1194376724, COSV100846447; called by muse, mutect2, varscan2
- RAB11B | c.511+1G>A p.X171_splice | Splice Site (SNP) | VAF 18/44 reads (41%) | catalogued as rs775363015, COSV100033230; called by muse, varscan2
- RAB27B | c.412C>T p.P138S | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV100024356; called by muse, mutect2, varscan2
- RAB41 | c.389G>A p.R130Q (on ENST00000374473 / NM_001363807.1; = p.R129Q on NM_001032726.3) | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.652); catalogued as rs765102291, COSV52105840; called by muse, mutect2, varscan2
- RABGEF1 | c.202T>C p.W68R (on ENST00000439720 / NM_001287061.2; = p.W55R on NM_014504.3 and 29 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.37); PolyPhen benign (0.038); catalogued as COSV99535140; called by muse, mutect2, varscan2
- RANBP17 | c.992G>A p.R331Q | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs764213241, COSV101206389; called by muse, mutect2, varscan2
- RAPGEF2 | c.4118C>T p.P1373L | Missense Mutation (SNP) | VAF 182/187 reads (97%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV100031672; called by muse, mutect2, varscan2
- RAPGEF5 | c.1423C>T p.P475S (on ENST00000401957 / NM_001367602.2; = p.P778S on NM_012294.5) | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1402018511, COSV59787134; called by muse, mutect2, varscan2
- RECQL4 | c.1303C>T p.P435S | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.272); catalogued as rs769553486, COSV99468265; called by muse, mutect2, varscan2
- REL | c.1107T>G p.H369Q | Missense Mutation (SNP) | VAF 51/104 reads (49%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as COSV99692421; called by muse, mutect2, varscan2
- RFX6 | c.724C>T p.P242S | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100263177; called by muse, mutect2, varscan2
- RICTOR | c.4088C>T p.T1363I | Missense Mutation (SNP) | VAF 53/103 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.787); catalogued as COSV99705771; called by muse, mutect2, varscan2
- RIF1 | c.3764C>T p.T1255I | Missense Mutation (SNP) | VAF 42/87 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as rs755656031, COSV99691274; called by muse, mutect2, varscan2
- RNASE6 | c.383C>T p.A128V | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100485957; called by muse, mutect2, varscan2
- RNASE9 | c.235C>T p.H79Y | Missense Mutation (SNP) | VAF 48/119 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV100141372; called by muse, mutect2, varscan2
- RNF145 | c.494T>C p.L165S (on ENST00000424310 / NM_001199383.2; = p.L193S on NM_144726.2) | Missense Mutation (SNP) | VAF 14/21 reads (67%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.478); catalogued as COSV99193879; called by muse, mutect2, varscan2
- ROBO1 | c.199C>T p.P67S | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.471); catalogued as COSV101459367; called by muse, mutect2, varscan2
- ROS1 | c.1312G>A p.V438I | Missense Mutation (SNP) | VAF 24/43 reads (56%) | SIFT tolerated (0.25); PolyPhen benign (0.015); catalogued as COSV100877718; called by muse, mutect2, varscan2
- RPS6KA6 | c.1325G>A p.R442Q | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.286); catalogued as rs1412435395, COSV99425480; called by muse, mutect2, varscan2
- RUBCN | c.278C>T p.P93L | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763725765, COSV56362460; called by muse, mutect2, varscan2
- RUBCN | c.277C>T p.P93S | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99585123; called by muse, mutect2, varscan2
- RUNX1T1 | c.1706C>T p.S569F (on ENST00000265814 / NM_001198628.1; = p.S542F on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.271); catalogued as COSV99755032; called by muse, mutect2, varscan2
- RXFP1 | c.1411G>A p.E471K | Missense Mutation (SNP) | VAF 41/64 reads (64%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.908); catalogued as COSV100314229; called by muse, mutect2, varscan2
- RXFP3 | c.666G>A p.W222* | Nonsense Mutation (SNP) | VAF 11/29 reads (38%) | catalogued as COSV100347808; called by muse, mutect2, varscan2
- RYR1 | c.6976T>G p.C2326G | Missense Mutation (SNP) | VAF 23/35 reads (66%) | SIFT deleterious (0.01); PolyPhen benign (0.123); catalogued as COSV100617048; called by muse, mutect2, varscan2
- SACS | c.8617C>T p.L2873F | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs779977899, COSV101207740; called by muse, mutect2, varscan2
- SALL4 | c.2744T>C p.V915A | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.986); catalogued as COSV99409866; called by muse, mutect2, varscan2
- SAMD12 | c.578C>T p.S193F | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT tolerated, low confidence (0.89); PolyPhen benign (0); catalogued as rs759841320, COSV100126386; called by muse, mutect2, varscan2
- SAMD9 | c.556G>A p.G186R | Missense Mutation (SNP) | VAF 65/129 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as rs377222750; called by muse, mutect2, varscan2
- SATB2 | c.1291C>T p.R431C | Missense Mutation (SNP) | VAF 31/59 reads (53%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as rs769604856, COSV53492855; called by muse, mutect2, varscan2
- SCG3 | c.376G>A p.G126R | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.027); catalogued as COSV99591243; called by muse, mutect2, varscan2
- SCN10A | c.2431G>A p.E811K | Missense Mutation (SNP) | VAF 27/49 reads (55%) | SIFT tolerated (1); PolyPhen benign (0.09); catalogued as rs77049337, COSV71860249; called by muse, mutect2, varscan2
- SCN11A | c.1955G>A p.S652N | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV100182611; called by muse, mutect2, varscan2
- SCN9A | c.1303G>A p.E435K | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.521); catalogued as rs775475997, COSV100314272; called by muse, mutect2, varscan2
- SCTR | c.314G>A p.R105Q | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1488194173, COSV50028107; called by muse, mutect2, varscan2
- SDK1 | c.1150+1G>A p.X384_splice | Splice Site (SNP) | VAF 3/15 reads (20%) | catalogued as COSV101269879; called by muse, mutect2
- SDK1 | c.6400G>A p.E2134K | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs774146423, COSV67354685; called by muse, mutect2
- SEC61A2 | c.313A>T p.T105S | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100036665; called by muse, mutect2
- SEL1L2 | c.811G>A p.E271K | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV53155536; called by muse, mutect2, varscan2
- SEMA5A | c.2251G>A p.E751K | Missense Mutation (SNP) | VAF 47/184 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs868269067, COSV66799175; called by muse, mutect2, varscan2
- SEMG2 | c.1177C>T p.P393S | Missense Mutation (SNP) | VAF 47/96 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.036); catalogued as COSV65647263, COSV65647834; called by muse, mutect2, varscan2
- SERPINA10 | c.343G>A p.G115R | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100004049; called by muse, mutect2, varscan2
- SERPINB11 | c.521C>T p.S174F | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as COSV101236338; called by muse, mutect2, varscan2
- SERPINB3 | c.645A>T p.Q215H | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99380252; called by muse, mutect2, varscan2
- SERPINB7 | c.491G>A p.S164N | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.491); catalogued as rs1253335288, COSV100321041; called by muse, mutect2, varscan2
- SERPINC1 | c.1075G>A p.D359N | Missense Mutation (SNP) | VAF 47/114 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV100875126; called by muse, mutect2, varscan2
- SERPINF2 | c.202G>A p.G68R | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs1459888831, COSV100132108; called by muse, mutect2, varscan2
- SERPINF2 | c.203G>A p.G68E | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV100132110; called by muse, mutect2, varscan2
- SERPINI2 | c.70C>T p.Q24* | Nonsense Mutation (SNP) | VAF 47/103 reads (46%) | catalogued as rs1389545333, COSV52986436, COSV52989203; called by muse, mutect2, varscan2
- SETDB2 | c.619C>T p.R207C | Missense Mutation (SNP) | VAF 71/182 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); catalogued as rs761497668, COSV99321026; called by muse, mutect2, varscan2
- SHANK1 | c.6131G>A p.G2044E | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.998); catalogued as COSV99522082; called by muse, mutect2, varscan2
- SHROOM4 | c.59C>T p.P20L | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV99174722; called by muse, mutect2, varscan2
- SIGLEC7 | c.555G>A p.M185I | Missense Mutation (SNP) | VAF 42/58 reads (72%) | SIFT tolerated (0.29); PolyPhen benign (0.012); catalogued as COSV99978924; called by muse, mutect2, varscan2
- SIGLEC8 | c.1019C>T p.S340F | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.708); catalogued as COSV58474239; called by muse, mutect2, varscan2
- SLC12A3 | c.2840C>T p.T947M (on ENST00000563236 / NM_001126108.2; = p.T956M on NM_000339.3) | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.205); catalogued as rs753841103, COSV99344784; called by muse, mutect2, varscan2
- SLC17A9 | c.890C>T p.S297F | Missense Mutation (SNP) | VAF 178/304 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV100948001; called by muse, mutect2, varscan2
- SLC25A21 | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58730784; called by muse, mutect2, varscan2
- SLC28A1 | c.1580C>T p.S527F | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV54476802; called by muse, mutect2
- SLC4A10 | c.1198T>A p.F400I (on ENST00000446997 / NM_001354461.2; = p.F370I on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99765847; called by muse, mutect2, varscan2
- SLC4A1AP | c.289C>T p.P97S | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV100389669; called by muse, mutect2, varscan2
- SLC4A9 | c.610G>A p.E204K (on ENST00000507527 / NM_001258428.2; = p.E180K on NM_031467.3) | Missense Mutation (SNP) | VAF 48/75 reads (64%) | SIFT tolerated (0.2); PolyPhen benign (0.01); catalogued as rs1045462839, COSV99139948; called by muse, mutect2, varscan2
- SLC5A5 | c.1054C>T p.L352F | Missense Mutation (SNP) | VAF 24/41 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99715377; called by muse, mutect2, varscan2
- SLC5A8 | c.964C>T p.L322F | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101610612; called by muse, mutect2, varscan2
- SLC7A10 | c.635-1G>A p.X212_splice | Splice Site (SNP) | VAF 18/23 reads (78%) | catalogued as COSV99472594; called by muse, mutect2, varscan2
- SLC7A7 | c.1460G>T p.C487F | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as CD000278, COSV99035515, COSV99591326; called by muse, mutect2, varscan2
- SLC7A7 | c.1459T>A p.C487S | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV99591328; called by muse, mutect2, varscan2
- SLC7A9 | c.547G>A p.A183T | Missense Mutation (SNP) | VAF 23/33 reads (70%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.838); catalogued as rs201766636, COSV99195359; called by muse, mutect2, varscan2
- SLC8A1 | c.2677C>T p.H893Y | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.783); catalogued as rs902641212, COSV100247474; called by muse, mutect2, varscan2
- SLC9A3 | c.930C>T p.L310= | Splice Region (SNP) | VAF 7/26 reads (27%) | catalogued as rs757315323, COSV53801445; called by muse, mutect2
- SLCO1B1 | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 35/131 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.288); catalogued as COSV57011804; called by muse, mutect2, varscan2
- SLCO1B1 | c.944G>A p.G315E | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs373619379; called by muse, mutect2, varscan2
- SLCO1C1 | c.1601C>T p.S534F | Missense Mutation (SNP) | VAF 32/99 reads (32%) | SIFT tolerated (0.73); PolyPhen benign (0.007); catalogued as COSV56878207, COSV99860050; called by muse, varscan2
- SLCO3A1 | c.922G>A p.E308K | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.36); PolyPhen benign (0.102); catalogued as COSV100575919; called by muse, mutect2, varscan2
- SLFN12 | c.221G>A p.G74E | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV100513229; called by muse, mutect2, varscan2
- SLFN5 | c.1100C>T p.S367L | Missense Mutation (SNP) | VAF 49/133 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs200108679, COSV55479923; called by muse, mutect2, varscan2
- SLITRK5 | c.316G>A p.G106R | Missense Mutation (SNP) | VAF 68/187 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.917); catalogued as COSV100281229; called by muse, mutect2, varscan2
- SMARCAL1 | c.1441C>T p.L481F | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.833); catalogued as COSV100620069; called by muse, mutect2, varscan2
- SMARCAL1 | c.1499G>T p.W500L | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as COSV100620070; called by muse, mutect2
- SNCAIP | c.2188G>A p.G730R | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.621); catalogued as COSV99750458; called by muse, mutect2, varscan2
- SNCG | c.304C>T p.P102S | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV100813846, COSV62318012; called by muse, mutect2, varscan2
- SNRPB | c.575C>T p.P192L | Missense Mutation (SNP) | VAF 36/70 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV100293506; called by muse, mutect2, varscan2
- SNX31 | c.808G>A p.G270R | Missense Mutation (SNP) | VAF 44/139 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61263544; called by muse, mutect2, varscan2
- SORCS3 | c.2551G>A p.D851N | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100863834; called by muse, mutect2, varscan2
- SORCS3 | c.3643G>A p.E1215K | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); catalogued as COSV100865668; called by muse, mutect2, varscan2
- SORL1 | c.1042G>A p.E348K | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs149041363, COSV52751449, COSV52751945; called by muse, mutect2, varscan2
- SOX17 | c.1133C>T p.P378L | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.516); catalogued as rs765609726, COSV52024427, COSV52028402, COSV99810860; called by muse, mutect2, varscan2
- SPANXN3 | c.186A>T p.K62N | Missense Mutation (SNP) | VAF 71/186 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV100980885; called by muse, mutect2, varscan2
- SPATA19 | c.434G>A p.R145Q | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT tolerated (0.08); PolyPhen benign (0.027); catalogued as rs779926857, COSV54482512; called by muse, mutect2, varscan2
- SPATA5L1 | c.1459C>T p.P487S | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.223); catalogued as COSV99973326; called by muse, mutect2, varscan2
- SPHKAP | c.996G>A p.M332I | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs868284456, COSV100764541, COSV60890356; called by muse, mutect2, varscan2
- SPRR2B | c.185C>T p.P62L | Missense Mutation (SNP) | VAF 47/130 reads (36%) | SIFT tolerated, low confidence (0.91); PolyPhen benign (0); catalogued as COSV100482348; called by muse, mutect2, varscan2
- SPRYD7 | c.370C>T p.P124S | Missense Mutation (SNP) | VAF 41/85 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.388); catalogued as COSV100709890; called by muse, mutect2, varscan2
- SPTLC3 | c.1144G>A p.G382R | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100983302; called by muse, mutect2, varscan2
- SPTLC3 | c.1465G>A p.G489R | Missense Mutation (SNP) | VAF 130/254 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1180743197, COSV100983303; called by muse, mutect2, varscan2
- SRGAP2 | c.2060C>T p.P687L (on ENST00000624873 / NM_001170637.4; = p.P688L on NM_015326.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 58/183 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.443); catalogued as COSV99833280; called by muse, mutect2, varscan2
- SRRM2 | c.4612C>T p.R1538C | Missense Mutation (SNP) | VAF 39/64 reads (61%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.333); catalogued as rs781505083, COSV57068882; called by muse, mutect2, varscan2
- SSX7 | c.8G>A p.G3E | Missense Mutation (SNP) | VAF 120/300 reads (40%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.721); catalogued as COSV99994018; called by muse, varscan2
- ST6GAL2 | c.581G>A p.R194K | Missense Mutation (SNP) | VAF 32/66 reads (48%) | PolyPhen benign (0.003); catalogued as COSV100867810, COSV100868301; called by muse, mutect2, varscan2
- ST6GALNAC5 | c.740G>A p.R247K | Missense Mutation (SNP) | VAF 39/114 reads (34%) | PolyPhen possibly damaging (0.855); catalogued as rs774760454, COSV100603094, COSV59563701; called by muse, mutect2, varscan2
- ST8SIA2 | c.272C>T p.T91M | Missense Mutation (SNP) | VAF 17/79 reads (22%) | PolyPhen probably damaging (0.977); catalogued as rs777052792, COSV51570496; called by muse, varscan2
- STAB2 | c.857G>A p.G286E | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101186332; called by muse, mutect2, varscan2
- STN1 | c.724C>T p.P242S | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.077); catalogued as COSV99830362; called by muse, mutect2, varscan2
- STON2 | c.184G>A p.D62N | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.756); catalogued as COSV50848211, COSV99965178; called by muse, mutect2, varscan2
- STPG4 | c.374C>T p.P125L | Missense Mutation (SNP) | VAF 36/69 reads (52%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.762); catalogued as COSV99681459; called by muse, mutect2, varscan2
- STRN | c.1204C>T p.P402S | Missense Mutation (SNP) | VAF 30/131 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.334); catalogued as COSV99814821; called by muse, mutect2, varscan2
- STYXL2 | c.3400G>A p.D1134N | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs758777256, COSV54805404; called by muse, mutect2, varscan2
- SV2A | c.1330C>T p.R444W | Missense Mutation (SNP) | VAF 57/137 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs117711516, COSV100975285, COSV64965879; called by muse, mutect2, varscan2
- SYNE1 | c.24779C>T p.S8260L (on ENST00000367255 / NM_182961.4; = p.S8189L on NM_033071.3) | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.663); catalogued as rs188852595, COSV55143014; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SYNE1 | c.2854G>A p.E952K (on ENST00000367255 / NM_182961.4; = p.E959K on NM_033071.3) | Missense Mutation (SNP) | VAF 41/66 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54915029; called by muse, mutect2, varscan2
- SYNE2 | c.7697C>T p.S2566F | Missense Mutation (SNP) | VAF 2/25 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); catalogued as rs906787422, COSV100648515; called by muse, mutect2
- SYNJ2 | c.3052G>A p.D1018N | Missense Mutation (SNP) | VAF 146/291 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.265); catalogued as rs771454251, COSV100840664; called by muse, mutect2, varscan2
- SYT9 | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.019); catalogued as COSV100609258; called by muse, mutect2, varscan2
- SYTL5 | c.1663C>T p.P555S | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.688); catalogued as rs770179535, COSV99937664; called by muse, mutect2, varscan2
- TACC2 | c.7576G>A p.E2526K (on ENST00000334433; = p.E604K on NM_006997.4) | Missense Mutation (SNP) | VAF 29/110 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99587783; called by muse, mutect2, varscan2
- TAF4B | c.718A>T p.K240* | Nonsense Mutation (SNP) | VAF 48/124 reads (39%) | catalogued as COSV99301002; called by muse, mutect2, varscan2
- TAFA2 | c.245C>T p.P82L | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101353966; called by muse, mutect2, varscan2
- TAS2R14 | c.806G>T p.G269V | Missense Mutation (SNP) | VAF 48/128 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.173); catalogued as rs1299968288, COSV101115633; called by muse, mutect2, varscan2
- TAS2R7 | c.392C>T p.S131F | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV53687816; called by muse, mutect2, varscan2
- TBC1D10C | c.467G>A p.G156E | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100408379; called by muse, mutect2, varscan2
- TBC1D8B | c.3166G>A p.E1056K | Missense Mutation (SNP) | VAF 52/132 reads (39%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as rs1191367273, COSV99345027; called by muse, mutect2, varscan2
- TBC1D9B | c.3178C>T p.R1060C (on ENST00000356834 / NM_198868.3; = p.R1043C on NM_015043.4) | Missense Mutation (SNP) | VAF 20/32 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs200438741, COSV62282529; called by muse, mutect2, varscan2
- TBCD | c.1573C>T p.P525S | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs757199429, COSV62806720; called by muse, varscan2
- TBL1X | c.451C>T p.R151* | Nonsense Mutation (SNP) | VAF 13/28 reads (46%) | catalogued as rs763813359, COSV54282018; called by muse, mutect2, varscan2
- TCEAL6 | c.199G>A p.E67K | Missense Mutation (SNP) | VAF 77/181 reads (43%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.616); catalogued as COSV65654120; called by muse, mutect2, varscan2
- TCFL5 | c.170T>A p.L57Q | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99416153; called by muse, mutect2, varscan2
- TCTE1 | c.1348G>A p.E450K | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.06); catalogued as COSV101025441; called by muse, mutect2, varscan2
- TDRD1 | c.514C>T p.R172C | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.998); catalogued as COSV99315174; called by muse, mutect2, varscan2
- TDRD1 | c.2980G>A p.G994R | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99315177; called by muse, mutect2, varscan2
- TEDDM1 | c.68T>A p.L23Q | Missense Mutation (SNP) | VAF 44/109 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100842976; called by muse, mutect2, varscan2
- TET1 | c.83G>A p.R28Q | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs773402594, COSV101018927; called by muse, mutect2, varscan2
- TEX55 | c.413C>G p.T138R | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.921); catalogued as rs777993427, COSV55210580, COSV99817827; called by muse, mutect2, varscan2
- TEX55 | c.737C>T p.S246L | Missense Mutation (SNP) | VAF 30/54 reads (56%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as rs780307320, COSV99817829; called by muse, mutect2, varscan2
- TF | c.1685G>A p.G562E | Missense Mutation (SNP) | VAF 65/121 reads (54%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV99396429; called by muse, mutect2, varscan2
- TFCP2L1 | c.919C>T p.P307S | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.53); catalogued as rs754244755, COSV99748803; called by muse, mutect2, varscan2
- TFEC | c.308G>A p.G103E | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.043); catalogued as rs767271300, COSV55399015; called by muse, mutect2, varscan2
- TG | c.7724C>T p.S2575F | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as rs771026858, COSV55082336; called by muse, mutect2, varscan2
- THBS1 | c.1954G>A p.D652N | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.974); catalogued as COSV99528453; called by muse, mutect2, varscan2
- TIAM1 | c.1987C>T p.H663Y | Missense Mutation (SNP) | VAF 55/130 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as COSV54540709; called by muse, mutect2, varscan2
- TIMD4 | c.703G>A p.D235N | Missense Mutation (SNP) | VAF 10/13 reads (77%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as COSV50855260; called by muse, mutect2, varscan2
- TJAP1 | c.83C>T p.S28F | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT tolerated (0.18); PolyPhen benign (0.073); catalogued as COSV99447550; called by muse, mutect2, varscan2
- TLL2 | c.1139G>A p.R380K | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); catalogued as COSV100780545; called by muse, mutect2
- TLN2 | c.221T>G p.M74R | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.716); catalogued as COSV100170110; called by muse, mutect2, varscan2
- TLR7 | c.91C>T p.P31S | Missense Mutation (SNP) | VAF 71/195 reads (36%) | SIFT tolerated (0.38); PolyPhen benign (0.347); catalogued as rs1218801965, COSV66124434; called by muse, mutect2, varscan2
- TLR7 | c.1741C>T p.Q581* | Nonsense Mutation (SNP) | VAF 104/254 reads (41%) | catalogued as COSV101028151; called by muse, mutect2, varscan2
- TMC2 | c.1938C>T p.I646= | Splice Region (SNP) | VAF 44/97 reads (45%) | catalogued as COSV100727992; called by muse, varscan2
- TMC3 | c.563C>T p.S188L | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs200653005, COSV63922239; called by muse, mutect2, varscan2
- TMC5 | c.1234C>T p.R412W (on ENST00000396229 / NM_001105248.1; = p.R166W on NM_024780.5) | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.394); catalogued as rs763938316, COSV99572879; called by muse, mutect2, varscan2
- TMEM106A | c.205C>T p.P69S | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as COSV100358003; called by muse, mutect2, varscan2
- TMEM200A | c.340C>T p.R114C | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.643); catalogued as rs763623830, COSV51660044; called by muse, mutect2, varscan2
- TMEM63C | c.2404C>T p.Q802* | Nonsense Mutation (SNP) | VAF 16/33 reads (48%) | catalogued as COSV100029809; called by muse, mutect2, varscan2
- TMPRSS12 | c.806G>A p.G269E | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756994379, COSV101269165; called by muse, mutect2, varscan2
- TMPRSS4 | c.568T>A p.S190T | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV101449431; called by muse, mutect2, varscan2
- TNFRSF21 | c.724C>T p.P242S | Missense Mutation (SNP) | VAF 17/28 reads (61%) | SIFT tolerated (0.21); PolyPhen benign (0.041); catalogued as COSV99729754; called by muse, mutect2, varscan2
- TNR | c.3205G>A p.E1069K | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.913); catalogued as COSV99691689; called by muse, mutect2
604 further variants in this file (128 protein-altering or splice-affecting, 434 silent, 42 other) are not listed here.
